Clinical report (de-identified scan), EXCEPTIONAL_RESPONDERS case ER-AD7D, project EXCEPTIONAL_RESPONDERS-ER (Exceptional Responders), specimen ER-AD7D-TTM1-A (Metastatic).

[page 1 of 75]
Location

Name

Address

Phone

Results

Surgical Pathology Exam

MyChart Results Release

MyChart Status: Pending

Result Information

Status

Provider Status

Final result

+4457

Ordered

+4457

Component Results

Component

SURGICAL PATHOLOGY REPORT

SURGICAL PATHOLOGY REPORT...

Patient Name

Med Rec #:

Specimen #:

Final Diagnosis:

A. BIOPSY OF ILEUM:

- STRIPS OF SMALL INTESTINAL MUCOSA SHOWING NO SPECIFIC DIAGNOSTIC HISTOPATHOLOGIC FINDINGS.

B. RANDOM BIOPSY OF COLON:

- COLON MUCOSA SHOWING NO SPECIFIC DIAGNOSTIC ABNORMALITIES.

+4457

Clinical Information:

RECTAL BLEEDING

HEMORRHOIDS

Specimen(s) Submitted:

A: Ileum

B: Random colon

Gross Description:

A. Ileum biopsy: The specimen, received in formalin fixative, consists of two irregularly-shaped fragments of pink-tan soft tissue, slightly less than

[page 2 of 75]
0.2 and 0.3 cm in maximum individual dimension. Totally embedded, wrapped, one cassette.

B. Random colon biopsy: The specimen, received in formalin fixative, consists of a multiple irregularly-shaped fragments of pink-tan soft tissue, from 0.1 to 0.25 cm. Totally embedded, wrapped, one cassette.

A1, B1

+4457

Microscopic Description:

HISTOLOGIC EXAMINATION PERFORMED. RESULTS SUMMARIZED UNDER "FINAL DIAGNOSIS."

Lab and Collection

Surgical Pathology Exam of +4456

Ordering Provider Info

Ordering User Office Phone Authorizing Provider Office Phone

Additional Information

Specimen ID Bill Type Client ID

Additional Information

Specimen Date Taken	Specimen Time Taken	Specimen Received Date	Specimen Received Time	Result Date	Result Time
+4456		+4456		+4456	

Additional Information

Order-Level Documents - +4452
EKG <Order> - Scan of +4452

Surgical Pathology Exam (Order

Pathology and Cytology
Order

Released By: Auto-released Date: +4455
Authorizing: MD Department:

Order History

Inpatient

Date/Time	Action Taken	User	Additional Information
+4455	Release		From Order:
+4455	Complete		
+4455	Result		Final

Order Information

Order Date/Time Release Date/Time Start Date/Time End Date/Time

Order Details +4455 +4455 +4455 +4455

[page 3 of 75]
Pat. Name Adm. Date Sex Age Location Relationship Allergies

Adm.

Birth Date

Diagnosis

(789.00)

ABDMNAL

PAIN UNSPCF

SITE,

(V10.05) HX

OF COLONIC

MALIGNANCY

+2469

Report for (MRN:)

TEST: Srg Path Rpt

Collected Date & Time:

+2469

Result Name	Results	Units	Reference Range
-------------	---------	-------	-----------------

Surg Path Report (NOTE)

(NOTE)

SURGICAL PATHOLOGY REPORT

Patient Name:

Med Rec #:

Specimen #:

Final Diagnosis:

Colonoscopic biopsy, Anastomosis @ 10 cm: BENIGN MILDLY DISTORTED COLONIC MUCOSA WITH HYPERPLASTIC CHANGE, SUGGESTIVE OF INCIPIENT HYPERPLASTIC POLYP. NEGATIVE FOR MALIGNANCY.

***Electronically Signed Out By ***

Clinical Information:

BX OF COLON CA CRAMPY ABD PAIN HEMORRHOIDS

Specimen(s) Submitted:

Bx anastomosis @ 10 cm

Gross Description:

Bx. anastomosis @ 10 cm: The specimen, received in formalin, consists of three irregularly shaped fragments of pink-tan soft tissue, averaging 0.2 cm. Totally embedded, one cassette.

A1

[page 4 of 75]
Terminal ID: [REDACTED]
Reporting per: [REDACTED]Age in years: [REDACTED]
Location: [REDACTED]

Date of Birth: [REDACTED]

Gender: [REDACTED]

Surgical Reports

SURGICAL REPORTS

+1823

PREOP DIAGNOSIS: RECURRENT RECTAL CARCINOMA.
PREOP INDICATION: RECURRENT COLORECTAL CANCER (DICTATED BY [REDACTED])
+1823 TREAT SYMPTOMS.

Date of Surgery: [REDACTED]
Surgeon: [REDACTED]

Assistant: [REDACTED]

Location: [REDACTED]

PostOp Diagnosis: Recurrent rectal cancer [REDACTED]

- Procedure: > 1. Abdominal exploration [REDACTED]
2. Lysis of adhesions for one hour.
3. En bloc resection of rectum with upper vagina.
4. Primary anastomosis.
5. Mobilization of the splenic flexure.
6. Proctoscopy.
7. Diverting loop ileostomy.
8. Intraoperative radiation therapy ([REDACTED])
9. Cystoscopy (Dictated by [REDACTED])
10. Bilateral ureteral stent placement.
11. Intraoperative consultation.
12. Partial vaginectomy.

Drainage: 1 Foley Catheter, 2 Jackson-Pratt Drains

After the patient had been induced into anesthesia, she was placed in the combined position with all pressure points appropriately padded. Dr. [REDACTED] Team then came in and placed preoperative ureteral stents... Dictated by [REDACTED]

We were asked for stents preoperatively for a planned colon resection. The patient was placed in the dorsal lithotomy position and under general endotracheal anesthesia underwent panendoscopy using a 22-French cystoscope using the 0-, 30-, and 70-degree lenses. The urethra was normal. Both ureteral orifices were normal in configuration and appearance. Bladder mucosa throughout entirely unremarkable. The bladder moved well also without any evidence of mass effect. Then, 5-French whistle-tip catheters were placed up both ureteral orifices and secured in place with an 18-French Foley catheter and tied with heavy silk to this and placed to separate drainage bags. The patient tolerated this portion of the procedure without difficulty.

As the case proceeded, [REDACTED] called me back into the operating room. Because of the previous radiation therapy, we were unable to feel either of the stents intraoperatively, and the tumor mass was clearly adherent to the vaginal vault. There was question as to whether or not it was invading the base of the bladder. Using an ERA sizer, we were able to direct the vagina posteriorly as well as laterally in order to gain access to the vesicovaginal plane and then were able to dissect the upper portion of the vagina away from the bladder itself. The bladder was uninjured at the completion of this resection. We were able to palpate both of the ureteral stents. They were also intact and out of the surgical field.

The stents will be treated post-operatively per usual, and I am happy to

[page 5 of 75]
(Continued)

see the patient should he require. I thank him very much for his consultation... Dictated by [REDACTED] +1823

After [REDACTED] Service had placed the preoperative ureteral stents, the patient was repositioned and prepped and draped, both the abdomen and the perineum in standard fashion. The patient's prior midline incision was completely removed, and the abdomen was entered in the upper abdomen through the upper aspect of her previous incision. We then dissected down and opened the entire incision without injury to the underlying bowel. Once we had done that, there were very few adhesions to the anterior abdominal wall. There were diffuse interloop adhesions of the small bowel and multiple adhesions to the side walls. We then spent the next hour to hour and 15 minutes taking down the adhesions. Eventually, we had the entire small bowel freed up. We then placed our retraction and began our exploration of the abdomen. Once both lobes of the liver were palpated and there was no evidence of metastatic disease, both diaphragms, the anterior wall of the stomach, the spleen, the pelvic sidewall, the anterior abdominal wall, and the small bowel were all without evidence of metastatic disease. Once this was done, we then placed our appropriate retraction and explored the pelvis. There was a focal area of thickening consistent with carcinoma between the anterior rectal wall, the top of the vagina, and the lower portion of the bladder. We first mobilized the left colon, taking down the splenic flexure. This allowed us then to divide the colon just above what appeared to be her previous anastomosis. We then divided the mesentery and entered into the presacral space without any difficulty. We then dissected posteriorly all the way down to approximately 4 cm from the pelvic floor and then became anterior. At this point in time, it was very difficult to determine where the trigone and the bladder were relative to this mass, and I asked Dr. [REDACTED] to scrub back in and help identify the anatomy of the bladder and ureters as they entered into the trigone. Once we had done that, we were able to then dissect the upper aspect of the vaginal cuff completely free from the bladder and carried this down all the way to the top of the rectum. Once we had divided the vagina and the specimen, we isolated the rectal tube distal to this and divided the rectum with a single firing of the TAGO thick tissue stapler. The specimen was sent off the field. I personally took it to Pathology and oriented them in regards to the specimen. They called back in and said a portion of the vaginal cuff was positive for microscopic adenocarcinoma. We then took another complete circumferential portion of the vagina basically down to the lower third of the vagina and sent this off for pathologic evaluation. They said the margins were all negative. We also sent any residual tissue in the area that had been close to the left side as redo margins, and these all came back negative. At this point in time, [REDACTED] scrubbed in and performed his IORT... Dictated by Dr. [REDACTED]

Following resection of the vaginal recurrence by [REDACTED], the specimen was evaluated in the Pathology Laboratory as well as an evaluation of the tumor bed. The initial margin was positive radially on the left side. Additional submitted tissue was negative for tumor. There was no gross residual disease remaining. There was an area on the left pelvic sidewall that was slightly roughened. It was close to the area that had the initial positive margin. It was elected to treat this area with intraoperative radiation therapy. The left pelvic sidewall vessels and nerves were within the IORT field as was the ureter. A 5.5-cm circular applicator with a 30-degree bevel was selected and placed into the pelvis and angled toward the left sidewall. Six sheets of lead were placed in the inferior pelvis to block the remaining rectum. The applicator was secured in position with the Bookwalter retractor, and the patient was docked to the linear accelerator. She received 1000 cGy with 9 MeV electrons to the 90% isodose depth. Following the completion of radiation, the patient was undocked from the accelerator. The applicator was removed, and the lead was removed. The surgical team then continued with the operation... Dictated by [REDACTED]

After the intraoperative radiation therapy was completed, I scrubbed back in with my service, and we performed our low rectal anastomosis with a 29-mm circular stapler. Both donuts were intact. Proctoscope was performed which showed good distention of the bowel proximal to the

[page 6 of 75]
(Continued)

anastomosis without evidence of compromise. I then sewed the vagina cuff closed. This was leaving the vagina approximately 1.5 cm deep. Dr. [redacted] then scrubbed back in and re-inspected the bladder and the ureters and found that there was no evidence of injury. We placed two No. 19 Jackson-Pratt drains in the deep pelvis behind the rectal anastomosis, secured them to the skin with 3-0 nylon. We then constructed our ileostomy site in the right lower quadrant and identified the terminal ileum that we would bring up as our ileostomy. We then placed multiple sheets of Seprafilm underneath the incision after irrigating and then closed the primary incision with interrupted No. 1 Vicryls. The skin was closed with 3-0 Monocryl. The stoma was matured with interrupted 3-0 Vicryls. Patient tolerated the procedure well and was taken to the recovery area in stable condition... Dictated by [redacted]

+1823

Wound Type: TYPE II - CLEAN-CONTAMINATED

Transcriptionist: [redacted]

Electronically Signed: [redacted]

PATHOLOGY REPORTS

Pathology Reports

+1823

Surgical Pathology

Requested By: [redacted]

Additional Physician: [redacted]

TISSUE DESCRIPTION:

[redacted] A1 A2 A3 A4 A5 A6 A7 A8 A9 B1 B2 B3 B4 B5 C1 C2 C3 D1 E1
18.0 cm segment of rectosigmoid with portion of vagina (3.5 x 3.2 cm), tissue from the left pelvic sidewall margin (2.6 x 2.5 x 1.5 cm), revision of the left vaginal margin (5.5 x 2.4 x 1.1 cm), tissue from the rectal mesentery (5.8 x 2.0 x 0.5 cm), and tissue from the left bladder edge (1.6 x 1.0 x 0.3 cm).

DIAGNOSIS:

Rectosigmoid and vagina, resection: Residual/recurrent invasive grade 3 (of 4) rectal adenocarcinoma forming a 2.8 x 2.2 x 1.5 cm mass in the anterior rectal soft tissue with extension into the vaginal sidewall. The vaginal and colonic mucosa are free of tumor. The radial (soft tissue) margin is positive for adenocarcinoma. The vaginal and colonic margins are negative for tumor. Multiple (10) regional lymph nodes are negative for tumor.

Soft tissue, left pelvic sidewall margin, biopsy: Negative for tumor.

Vaginal margin, revision: Benign squamous mucosa and fibromuscular tissue, no tumor present.

Rectum, mesentery biopsy: Adipose tissue with hemorrhage. No tumor present ([redacted]).

Bladder, left edge, biopsy: Benign fibroadipose tissue, no tumor present ([redacted]).

[page 7 of 75]
+1705

Path Review of Outside Specimen ([REDACTED])

Referring Physician: [REDACTED]

Requested By: [REDACTED]

1665

DIAGNOSIS:
Vaginal cuff, biopsy [REDACTED] Involved by grade 3 (of
4) adenocarcinoma, morphologically consistent with colorectal
primary. +1706

Electronically signed by [REDACTED] +1706

SPECIMEN DESCRIPTION:
A: Clinic Consult Material

TISSUE DESCRIPTION:

MATERIAL RECEIVED:
vaginal biopsy - 1 slide [REDACTED]
SLIDE DISPOSITION:
1 slide returned [REDACTED] +1713

*** End of data ***

[page 8 of 75]
+3699

Go to...

Report for [REDACTED]

TEST: Srg Path Rpt [REDACTED]
Collected Date & Time: [REDACTED] +1666

Result Name	Results	Units	Reference Range
Surg Path Report	(NOTE)(..)		

(NOTE)
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]

Med Rec #: [REDACTED]

Specimen #: [REDACTED]

Final Diagnosis:

Vaginal cuff, biopsy: ADENOCARCINOMA. SEE COMMENT.

Comment:

Clinical history indicates that this patient has had colon carcinoma. Those slides are not available for our review, but this lesion is compatible with colon primary. This lesion, although primarily an adenocarcinoma, shows areas suggesting squamous differentiation, which, if it is metastatic from the colon, would suggest an origin near the pectinate line. Overlying vaginal squamous epithelium does not show any preneoplastic atypical change.

[REDACTED] +1670

***Electronically Signed Out By [REDACTED] **

Clinical Information:

VAGINAL CUFF GROWTH HISTORY OF COLON CA

Specimen(s) Submitted:

Vaginal biopsy

Gross Description:

Biopsy vaginal cuff: The specimen, received in formalin, consists of are two fragments of tan-gray rubbery tissue, measuring 0.5 x 0.4 x 0.3 cm in aggregate. Totally embedded, one cassette.

A1

+1667

[page 9 of 75]
Patient:
Unit#/Acct#:
Location:
Att Phys-Serv:
Ordering Phys:
Referring Phys:

DOB: [redacted] Sex: [redacted]
Case#: [redacted]
Accn#: [redacted]
Completed: [redacted] +518
Received: [redacted] +518
Collected: [redacted] +518

***** NON-GYNE I *****

Specimen(s): Pelvic Washings

Primary Diagnosis: NO MALIGNANT CELLS SEEN

Amount Received: 30-40 mls

Specimen Description: Yellow

Performed By:

Electronic Signature:

End of Report -

+518

Final

[page 10 of 75]
[REDACTED]
[REDACTED]
[REDACTED] **Converted Surgical**
*** Converted Case *** This report may not match the original report format

Patient Name: [REDACTED]
Med Rec #: [REDACTED]
DOB: [REDACTED]
Gender: [REDACTED]
Physician(s): [REDACTED]

Specimen #: [REDACTED]
Date of Procedure: [REDACTED]
Date of Receipt: [REDACTED]
Date of Report: [REDACTED] +525
Location: [REDACTED]

FINAL DIAGNOSIS:

PATHOLOGIST IS [REDACTED] A [REDACTED] Ileocecal valve biopsy;
FRAGMENTS OF COLONIC MUCOSA SHOWING PROMINENT MUCOSAL LYMPHOID AGGREGATE
BUT WITHOUT EVIDENCE OF ACTIVE INFLAMMATION, ULCERATION OR MALIGNANCY.
B. Terminal ileum biopsy; NON-DIAGNOSTIC FRAGMENTS OF SMALL BOWEL
MUCOSA. [REDACTED]

+525

***Electronically Signed Out by Conversion *** [REDACTED]

Specimen(s) Submitted:

Conversion specimen with no parts

Gross Description:

+525 [REDACTED] A. Ileocecal valve biopsy; The specimen, received in
formalin fixative, consists of two irregularly-shaped fragments of
pink-tan soft tissue, each measuring 3 mm in diameter. Totally embedded,
one cassette. B. Terminal ileum biopsy; The specimen, received in
formalin fixative, consists of two irregularly-shaped fragments of
pink-tan soft tissue, each measuring 4 mm in diameter. Totally embedded,
one cassette. [REDACTED]

Other Related Clinical Data:

ELEVATED CEA LEVELS - HEMORRHOIDS ORDERING PHYSICIAN IS [REDACTED]

[page 11 of 75]
Completed: [REDACTED]
Spec. Type: Peritoneum, Bx
Result name +218

Collected: [REDACTED]
Result

+217

Surgeon: [REDACTED]
Additional Physician: [REDACTED]
Clinical Data: SMALL BOWEL RESECTION
Gross Description:

A. Peritoneal biopsy: The specimen, received in formalin fixative, consists of a 1.7 x 0.7 x 0.3 cm fragment of tissue with apparent glistening serosal lining, pink-tan in color, and a slightly edematous character on section. Totally embedded, one cassette.

B. Pelvic nodule: The specimen, received in formalin fixative, consists of a 1.3 x 0.4 x 0.3 cm rough surface fragment of pink-tan to hemorrhagic soft tissue. Totally embedded, one cassette.

A/Date: [REDACTED] 1

*DUPLICATE SURGICAL PATHOLOGY R [REDACTED]

+217

+234

Completed: [REDACTED]
Spec. Type: Peritoneum, Bx
Result name +218

Collected: [REDACTED]
Result

+217

C. Appendix: The specimen, received in formalin fixative, consists of a 7 x 0.4 x 0.4 cm, grossly unremarkable vermiform appendix with mesoappendix 1.5 cm. Section shows an open lumen over the proximal 2.5 cm, but apparent fibrous obliteration distal to this. The adipose tissue is dissected off and all of the appendiceal tissue is sectioned and embedded in two cassettes.

Pathologic Diagnosis: +217

+234

A/Date: [REDACTED]

*DUPLICATE SURGICAL PATHOLOGY [REDACTED]

Completed: [REDACTED]
Spec. Type: Peritoneum, Bx
Result name +218

Collected: [REDACTED]
Result

+217

A. Peritoneal biopsy: CONNECTIVE TISSUE WITH SEROSAL COVERING CONSISTENT WITH FIBROVASCULAR ADHESION.

B. Pelvic peritoneum, biopsy of nodule: FIBROCOLLAGENOUS CONNECTIVE TISSUE WITH BLOOD VESSEL SHOWING NON-SPECIFIC MURAL CALCIFICATION.

C. Vermiform appendix, incidental appendectomy: VERMIFORM APPENDIX WITHOUT DIAGNOSTIC ABNORMALITY. THE DISTAL APPENDIX SHOWS FIBROADIPOSE OBLITERATION OF THE LUMEN (NON-SPECIFIC CHANGE). [REDACTED]

Electronic Signature: [REDACTED]

End of Report!

[page 12 of 75]
TISSUE REPORT

Patient: [REDACTED]

Med. Rec. # [REDACTED]

Date: [REDACTED]

+0

Physician: [REDACTED]

Copy to: [REDACTED]

Copy to: [REDACTED]

Sex: [REDACTED]

Age: [REDACTED]

Financial #: [REDACTED]

Spec#: [REDACTED]

CLINICAL INFORMATION

ANEMIA

SPECIMEN SUBMITTED

- A) CA COLON-DISTAL DESCENDING COLON
- B) SIGMOID POLYP

PATHOLOGIC DIAGNOSIS

- PART A: DISTAL DESCENDING COLON: ADENOCARCINOMA, MODERATELY DIFFERENTIATED.
- PART B: SIGMOID POLYP: TUBULAR ADENOMA, NEGATIVE FOR MALIGNANCY.

FOR QUALITY ASSURANCE PURPOSES, THIS CASE HAS BEEN REVIEWED BY ANOTHER DEPARTMENT MEMBER [REDACTED] AND SHE CONCURS WITH THE DIAGNOSIS.

TR1

+4

GROSS DESCRIPTION

PART A: THE SPECIMEN IS COMPRISED OF SIX IRREGULAR SOFT TAN FRAGMENTS OF MUCOSAL TISSUE, RANGING FROM 1 TO 3 MM IN MAXIMUM DIAMETER, ALL EMBEDDED.

PART B: THE SPECIMEN IS COMPRISED OF A SINGLE IRREGULAR SOFT TAN FRAGMENT OF MUCOSAL TISSUE, MEASURING 2 MM IN DIAMETER, ALL EMBEDDED.

Performed: [REDACTED] By: [REDACTED] M.D.

+4

MICROSCOPIC DESCRIPTION

PART A: SECTIONS OF SPECIMEN A REVEAL MUCOSAL BIOPSY OF THE COLON SHOWING MODERATELY DIFFERENTIATED ADENOCARCINOMA. ULCERATION IS ALSO IDENTIFIED.

PART B: SECTIONS OF SPECIMEN B REVEAL COLONIC MUCOSAL BIOPSY SPECIMEN SHOWING TUBULAR ADENOMA. THERE IS NO EVIDENCE OF MALIGNANCY.

[page 13 of 75]
[REDACTED]

CYTOLOGY REPORT

Patient: [REDACTED] Sex: [REDACTED] Age: [REDACTED]
Med. Rec. #: [REDACTED] Room/Bgd: [REDACTED] Financial #: [REDACTED]
Admitted: [REDACTED] Physician: [REDACTED] Spec#: [REDACTED] +0
-1 Copy to: [REDACTED] Collected: [REDACTED] +1
Copy to: [REDACTED] Received: [REDACTED]

SPECIMEN

PERITONEAL FLUID

GROSS DESCRIPTION

10 ML BLOODY FLUID

CLINICAL INFORMATION

NO CLINICAL HISTORY PROVIDED

STATEMENT OF ADEQUACY

SATISFACTORY FOR EVALUATION.

DESCRIPTIVE INTERPRETATION

ATYPICAL CELLS PRESENT.

COMMENTS/RECOMMENDATIONS

MESOTHELIAL CELLS, HISTIOCYTES, GRANULOCYTES AND LYMPHOCYTES.

+3

PERFORMED: [REDACTED]

[page 14 of 75]
TISSUE REPORT

Patient: [REDACTED] Sex: [REDACTED] Age: [REDACTED]
Med. Rec. #: [REDACTED] Room/Bed: [REDACTED] Financial #: [REDACTED]
Date: [REDACTED] Physician: [REDACTED] Spec#: [REDACTED]
Copy to: [REDACTED]
Copy to: [REDACTED]

CLINICAL INFORMATION OVARIAN TUMOR

SPECIMEN SUBMITTED

- A) LEFT OVARIAN TUMOR #FS B) COLON FOR PERMANENT
C) PROXIMAL LINE OF COLON D) DISTAL LINE OF COLON
E) OMENTUM F) UTERUS BILATERAL TUBES AND OVARIES
G) LEFT PELVIC TUMOR H) LEFT PELVIC LYMPH NODES
I) RIGHT COMMON ILIAC LYMPH NODE J) PARA-AORTIC LYMPH NODE

FROZEN SECTION DIAGNOSIS

ADENOCARCINOMA OF LEFT OVARY WITH MASSIVE NECROSIS AND HEMORRHAGE. [REDACTED]

Performed: [REDACTED] By: [REDACTED]
+3

PATHOLOGIC DIAGNOSIS

PART A: LEFT OVARIAN TUMOR: LEFT OVARY WITH METASTATIC COLONIC ADENOCARCINOMA.

PART B: COLON:

- A) INVASIVE, MODERATELY DIFFERENTIATED ADENOCARCINOMA INVADING THROUGH THE MUSCULARIS PROPRIA INTO THE SUBSEROA.
B) RADIAL RESECTION MARGIN FREE OF TUMOR.
C) TWO OF SIX OF LYMPH NODES WITH METASTATIC ADENOCARCINOMA (2/6).

PART C: PROXIMAL LINE OF COLON: PROXIMAL MARGIN WITH NO EVIDENCE OF TUMOR.

PART D: DISTAL LINE OF COLON: DISTAL MARGIN WITH NO EVIDENCE OF TUMOR.

PART E: OMENTUM: FIBROADIPOSE TISSUE WITH ACUTE AND CHRONIC INFLAMMATION AND NO EVIDENCE OF MALIGNANCY.

PART F: UTERUS, BILATERAL FALLOPIAN TUBES, AND RIGHT OVARY:

- A) NO EVIDENCE OF COLONIC ADENOCARCINOMA.
B) MULTIPLE LEIOMYOMAS
C) PROLIFERATIVE ENDOMETRIUM
D) CHRONIC CERVICITIS
E) BILATERAL FALLOPIAN TUBES AND RIGHT OVARY WITHOUT DIAGNOSTIC

[page 15 of 75]
TISSUE REPORT

Patient: [REDACTED] Sex: [REDACTED] Age: [REDACTED]
Med. Rec. #: [REDACTED] Room/Bed: [REDACTED] Financial #: [REDACTED]
Date: [REDACTED] Physician: [REDACTED] Spec#: [REDACTED]
+0 Copy to: [REDACTED]
Copy to: [REDACTED]

PATHOLOGIC DIAGNOSIS ABNORMALITY.

PART G: LEFT PELVIC TUMOR: METASTATIC COLONIC ADENOCARCINOMA.

PART H: LEFT PELVIC LYMPH NODE: ONE LYMPH NODE WITH NO EVIDENCE OF METASTATIC ADENOCARCINOMA (0/1).

PART I: RIGHT COMMON ILIAC LYMPH NODE: TWO LYMPH NODES WITH NO EVIDENCE OF METASTATIC ADENOCARCINOMA (0/2).

PART J: PARA-AORTIC LYMPH NODE: ONE LYMPH NODE WITH NO EVIDENCE OF METASTATIC ADENOCARCINOMA (0/1).

TR1

+3

By: [REDACTED]

COMMENTS/RECOMMENDATIONS

COLON CANCER SUMMARY

TUMOR TYPE : ADENOCARCINOMA

HISTOLOGIC GRADE : MODERATELY DIFFERENTIATED.

EXTENT OF INVASION: INVADES THROUGH MUSCULARIS PROPRIA INTO SUBSEROA OR PERIRECTAL SOFT TISSUES

MARGINS : 1) PROXIMAL: FREE
2) DISTAL : FREE
3) DEEP (RADIAL) FREE

LYMPHOVASCULAR (SMALL VESSEL) INVASION: ABSENT

VENOUS (LARGE) VESSEL INVASION : ABSENT

PERINEURAL INVASION : ABSENT

[page 16 of 75]
TISSUE REPORT

Patient: [REDACTED] Sex: [REDACTED] Age: [REDACTED]
Med. Rec. #: [REDACTED] Room/Bed: [REDACTED] Financial #: [REDACTED]
Date: [REDACTED] Physician: [REDACTED] Spec#: [REDACTED]
+0 Copy to: [REDACTED]
Copy to: [REDACTED]

COMMENTS/RECOMMENDATIONS

TUMOR BORDER CONFIGURATION : INFILTRATING

LYMPH NODES : TOTAL #9 INVOLVED #2

ADDITIONAL PATHOLOGIC FINDINGS: DIVERTICULOSIS.

T3 N1 M1 : (THE PATHOLOGIC STAGE IS BASED ON INFORMATION IN THIS REPORT, THEREFORE, CLINICAL STAGE MAY DIFFER). SEE COMMENT.

COMMENT: THE TUMOR HAS BEEN CLASSIFIED AS T3 N1 M1 AS IF THE LEFT OVARIAN TUMOR IS A DISTANT METASTASIS. IF IN FACT, THE TUMOR IS DIRECTLY EXTENDING FROM THE COLON INTO THE LEFT OVARY, THE TUMOR WOULD BE BEST CLASSIFIED AS T4 N1 M0. CORRELATE CLINICALLY.

GROSS DESCRIPTION

+0
AT THE TIME OF SURGERY [REDACTED] SPECIMEN A, LABELLED LEFT OVARIAN TUMOR SENT FOR FROZEN SECTION IS RECEIVED.

PART A: THE SPECIMEN IS COMPRISED OF A LARGE OVAL TO ROUND SOFT TO SLIGHTLY FIRM MASS WEIGHING 773.8 GRAMS, MEASURING 13 X 12 X 7 CM. THE CAPSULAR SURFACE PRESENTS SEVERAL ENGORGED BLOOD VESSELS. IN ONE AREA THERE IS AN NODULE PROTRUDING FROM THE SURFACE. THE TISSUE HAS BEEN PREVIOUSLY SLICED OPEN BY THE SURGEON, REVEALING A MARKEDLY NECROTIC SOFT TO SLIGHTLY FIRM GRAYISH WHITE TO GRAYISH YELLOW TISSUE OCCUPYING THE LARGE MASS. PARTS OF THE MASS APPEAR TO BE CYSTIC. ALMOST 80% IS SOLID AND SHOWS MARKED NECROSIS. SECTIONS TAKEN FOR FROZEN SECTIONS ARE LABELLED FS1, 2 AND 3. THE ENTIRE SPECIMEN WILL BE FIXED OVERNIGHT AND PROCESSED AFTER OVERNIGHT FIXATION. [REDACTED]

PART B: THE SPECIMEN CONSISTS OF A RESECTED SEGMENT OF COLON WHICH MEASURES 11 CM IN ITS LENGTH. ON OPENING THE COLON, THERE IS AN ULCERATED AREA IN THE MIDDLE OF COLON WHICH MEASURES 3.5 CM IN ITS WIDTH AND INVOLVED THE COLON IN A NAPKIN RING FASHION. ON SECTIONING THROUGH THE LESION, IT APPEARS TO BE A LESION INVOLVING THE WALL OF THE COLON. THE EXTENT OF INVOLVEMENT WILL BE DETERMINED ON MICROSCOPIC EXAMINATION. ON THE OUTER SURFACE OF THE COLON CAN BE SEEN A SMALLER SEGMENT OF BOWEL, WHICH MEASURES 5 CM IN ITS

[page 17 of 75]
TISSUE REPORT

Patient: [REDACTED] Sex: [REDACTED] Age: [REDACTED]
Med. Rec #: [REDACTED] Room/Bed: [REDACTED] Financial #: [REDACTED]
Date: [REDACTED] Physician: [REDACTED] Spec#: [REDACTED]
+0 Copy to: [REDACTED]
Copy to: [REDACTED]

GROSS DESCRIPTION

LENGTH AND IS SEEN ATTACHED TO THE MESENTERY. THE GROSSLY DESCRIBED LESION IS 4 CM FROM ONE LINE OF RESECTION AND 2.5 CM FROM THE OTHER LINE OF RESECTION. ON OPENING THIS SMALLER SEGMENT OF BOWEL WHICH IS ATTACHED TO THE MESENTERY, THE MUCOSA SHOWS NO EVIDENCE OF TUMOR OR ULCERATION. DIVERTICULOSIS IS IDENTIFIED.

SECTIONS ARE SUBMITTED AND LABELLED AS FOLLOWS: 1-4= FROM THE LINE OF RESECTION WITH THIS 4 CM FROM THE LESION. 5=SECTIONS FROM THE LINE OF RESECTION WHICH IS 2.5 CM FROM THE LESION, 6-7=SECTIONS FROM THIS LOOP OF BOWEL, 8-15=FROM POSSIBLE LYMPH NODES.

PART C: THE SPECIMEN CONSISTS OF A PORTION OF COLONIC TISSUE WHICH IS LINEAR, MEASURING 3 CM IN ITS LENGTH. THE ENTIRE SPECIMEN IS SUBMITTED.

PART D: THE SPECIMEN CONSISTS OF A RING OF BOWEL WHICH MEASURES 1.5 CM IN ITS MAXIMUM DIMENSION. IT HAS MULTIPLE STAPLES IN IT. REPRESENTATIVE SECTION TO INCLUDE THE ENTIRE LINE OF RESECTION IS SUBMITTED.

PART E: THE SPECIMEN CONSISTS OF 374 GRAMS OF OMENTUM. NO GROSS TUMOR IS IDENTIFIED IN THE OMENTUM. REPRESENTATIVE RANDOM SECTIONS ARE SUBMITTED.

PART F: THE SPECIMEN CONSISTS OF UTERUS, BILATERAL TUBES AND ONE SIDED OVARY. THE SPECIMEN WEIGHS 117.7 GRAMS. THE UTERUS AND CERVIX TOGETHER MEASURE 8 X 6 X 4.5 CM. THE ATTACHED OVARY MEASURES 4 X 1.5 X 1.5 CM. THE TUBE ON THE SIDE OF THE ATTACHED OVARY MEASURES 7 X 1 CM. THE TUBE ON THE OTHER SIDE MEASURES 6 X 1 CM. THE OVARY IS COARSELY WRINKLED, AND ON SECTIONING IT SHOWS ORDERLY APPEARANCE. SECTION FROM THIS TUBE AND OVARY ARE LABELLED 1 AND 2. SECTIONS FROM THE OTHER TUBE ARE LABELLED 3. ON OPENING THE UTERUS, THE MYOMETRIUM IS TAN AND TRABECULATED. THERE ARE NUMEROUS INTRAMURAL LEIOMYOMAS, THE LARGEST MEASURES 3 CM. THE ENDOMETRIUM IS TAN AND SMOOTH. THE ENDOCERVIX IS TAN AND SOMEWHAT MUCOID. THE EXOCERVIX IS THICKENED. SECTIONS FROM THE UTERUS TO INCLUDE THE ENDOMETRIUM, LEIOMYOMAS AND MYOMETRIUM ARE LABELLED 4 THROUGH 7 AND SECTION FROM THE CERVIX IS LABELLED 8.

PART G: THE SPECIMEN CONSISTS OF A GRAY TAN TISSUE, WHICH MEASURES 2 CM IN ITS GREATEST DIMENSION. THE ENTIRE SPECIMEN IS SUBMITTED.

PART H: THE SPECIMEN CONSISTS OF TWO YELLOWISH TO TAN TISSUES, THE LARGER MEASURES 2 CM. THE ENTIRE SPECIMEN IS SUBMITTED.

[page 18 of 75]
TISSUE REPORT

Patient: [REDACTED] Sex: [REDACTED] Age: [REDACTED]
Med. Rec #: [REDACTED] Room/Bed: [REDACTED] Financial #: [REDACTED]
Date: [REDACTED] Physician: [REDACTED] Spec#: [REDACTED]
+0 Copy to: [REDACTED]
Copy to: [REDACTED]

GROSS DESCRIPTION

PART I: THE SPECIMEN CONSISTS OF YELLOW GREASY TISSUE CONTAINING LYMPH NODES. THE SPECIMEN MEASURES 3 CM IN ITS MAXIMUM DIMENSION. THE SPECIMEN IS SECTIONED AND SUBMITTED IN TOTO IN TWO BLOCK SECTIONS.

PART J: THE SPECIMEN CONSISTS OF A YELLOW TO TAN TISSUE, MEASURING 1.5 CM. THE SPECIMEN IS BISECTED AND SUBMITTED IN TOTO.

Performed: [REDACTED] By: [REDACTED]
+3

MICROSCOPIC DESCRIPTION

PART A. SECTIONS SHOW THAT THE OVARY HAS BEEN ENTIRELY REPLACED BY A NECROTIC INVASIVE METASTATIC ADENOCARCINOMA. THE TUMOR IS INVADING THROUGHOUT AND EXTENSIVELY HEMORRHAGIC AND NECROTIC BACKGROUND. NO RESIDUAL NORMAL OVARIAN PARENCHYMA IS IDENTIFIED. THE TUMOR HAS A SIMILAR MORPHOLOGIC APPEARANCE TO THAT WHICH IS SEEN IN THE COLONIC PRIMARY.

PART B: SECTIONS OF COLON DEMONSTRATE AN INVASIVE, MODERATELY DIFFERENTIATED ADENOCARCINOMA INVADING THROUGH THE MUSCULAR PROPRIA TO THE PERICOLONIC FAT. ARCHITECTURALLY, THE CONSISTS OF COHESIVE NEOPLASTIC GLAND STRUCTURES INVADING THROUGHOUT AN INFLAMED DESMOPLASTIC STROMA. THE GLANDS SHOW CRIBRIFORMING AND ARE LINED BY NEOPLASTIC CELLS SHOWING NUCLEAR HYPERCHROMASIA, PLEOMORPHISM, AND COARSE CHROMATIN. NECROTIC DEBRIS AND CALCIFICATIONS ARE IDENTIFIED WITHIN NEOPLASTIC GLAND LUMENS. THE TUMOR HAS AN INVASIVE BORDER. DISTINCT LYMPHOVASCULAR SPACE INVASION IS NOT IDENTIFIED.

A SECTION FROM THE ATTACHED LOOP OF BOWEL SHOWS ILEAL MUCOSA WITHOUT DIAGNOSTIC ABNORMALITY. THE PROXIMAL AND DISTAL RESECTION MARGINS HAVE BEEN SEPARATELY SUBMITTED (PARTS C AND D). THE RADIAL RESECTION MARGIN IS FREE OF TUMOR. SIX PERICOLONIC LYMPH NODES ARE IDENTIFIED, TWO OF WHICH SHOW METASTATIC ADENOCARCINOMA. IN OTHER AREAS, METASTATIC TUMOR DEPOSITS ARE IDENTIFIED WITHIN FATTY TISSUE.

PARTS C THROUGH I: HISTOLOGIC EXAMINATION PERFORMED. RESULTS SUMMARIZED UNDER 'PATHOLOGIC DIAGNOSIS.'

[page 19 of 75]
TISSUE REPORT

Patient: [REDACTED] Sex: [REDACTED] Age: [REDACTED]
Med. Rec. #: [REDACTED] Room/Bed: [REDACTED] Financial #: [REDACTED]
Date: [REDACTED] Physician: [REDACTED] Spec#: [REDACTED]
+1 Copy to: [REDACTED]
Copy to: [REDACTED]

CLINICAL INFORMATION

PELVIC MASS PROBABLY OVARIAN CA, SIGMOID

SPECIMEN SUBMITTED

CELL BLOCK PERITONEAL FLUID.

PATHOLOGIC DIAGNOSIS

CELL BLOCK, PERITONEAL FLUID:
A) MOSTLY BLOOD WITH FEW MESOTHELIAL CELLS.
B) NEGATIVE FOR MALIGNANCY.

TR1 +3

By: [REDACTED]

GROSS DESCRIPTION

10 CC BLOODY FLUID.

Performed: [REDACTED] By: [REDACTED]

+3

MICROSCOPIC DESCRIPTION

SEE DIAGNOSIS.

[page 20 of 75]
Converted History

* Converted Case * This report may not match the original report format

Patient Name
Med Rec #
DOB
Gender
Physician(s)

Specimen #
Date of Procedure -7405
Date of Receipt
Date of Report +220
Location

FINAL DIAGNOSIS:

94/82 - - PATHOLOGIC DIAGNOSIS; D&C; ENDOMETRIUM,
SECRETORY TYPE, BENIGN.

-11373 - - PATHOLOGIC DIAGNOSIS; 1. CERVIX, 9
O'CLOCK; SQUAMOUS CARCINOMA IN-SITU OF CERVIX, SEEN IN ONE VERY SMALL
PIECE ONLY. CHRONIC CERVICITIS WITH SQUAMOUS METAPLASIA AND MILD FOCAL
CERVICAL DYSPLASIA. 2. D&C; ENDOMETRIAL AND ENDOCERVICAL TISSUE
SHOWING NO EVIDENCE OF MALIGNANCY. NOTE; THERE IS NO EVIDENCE OF INVASIVE
GROWTH. DRS. AGREE WITH THIS DIAGNOSIS.

-7720 - - GYNE; CLASS III. THE SMEARS SHOW DRYING
EFFECT.
ENTERED +220

***Electronically Signed Out by Conversion ***

Specimen(s) Submitted:

Tissue N/A

Other Related Clinical Data:

ORDERING PHYSICIAN IS

[page 21 of 75]
PATIENT: [REDACTED]
DATE OF BIRTH: [REDACTED]

PHYSICIAN: [REDACTED]

Date of Service: [REDACTED] +2006

PET WHOLE BODY, colon, restaging;
abnormal CT scan

RADIOPHARMACEUTICAL: 16.7 mCi F-18 fluorodeoxyglucose (FDG), IV, injected through right antecubital vein.

-347

CLINICAL: This is a [REDACTED] with a history of colon carcinoma diagnosed on [REDACTED]. Partial colonic resection was performed. There is a given history of hysterectomy. The patient received radiation and chemotherapy which ended on [REDACTED]. Recently performed CT examination demonstrated abnormal findings. The examination is performed for restaging of the disease.

+1732

TECHNIQUE: The patient's fasting blood glucose level was 116 mg/dl. Approximately 60 minutes after injection of the radiopharmaceutical, PET imaging from the base of the brain to the proximal thighs was performed with whole body attenuation-correction. Images were reconstructed into transaxial, coronal, and sagittal planes for interpretation.

+1889

FINDINGS: Comparison is made to the prior whole body PET scan of [REDACTED]. No hypermetabolic lesion was noted. Provided CT scan abdomen and pelvis report of [REDACTED] from [REDACTED] reported a few prominent sized retroperitoneal nodes. No pelvic adenopathy is reported. There is a diffuse thickening of the urinary bladder wall measuring up to 1.1 cm.

+1976

In the present examination, hypermetabolic metastatic mediastinal nodes are present within right inferior tracheobronchial, left perivascular and left hilar nodes with SUV up to 4.3. This abnormality was not present in the previous study. There is an elongated area of hypermetabolism along the anterolateral aspect of lower left rib with SUV 6.1. Bony metastasis is suspected.

There are several hypermetabolic metastatic retroperitoneal nodes, extending from level of adrenals down to the aortic bifurcation. Some of the nodes are smaller and some of them are enlarged. SUV reaches up to 5.5. One metastatic node is present in the left posterior paraspinal region at the level of left adrenal. No discrete lesion is noted within adrenal. There is a large, intensely hypermetabolic node along sidewall of the left lower pelvis with SUV up to 6.4. No abnormalities are seen in the urinary bladder area or surrounding the urinary bladder. There is a hypermetabolic focus inferior to the urinary bladder with SUV 6.9. I believe the findings either represent FDG secretion into the urethra or rectum.

[page 22 of 75]
PATIENT: [REDACTED]

[REDACTED] +2006

Page 2

No abnormalities are seen in the liver. The liver is mildly enlarged. There is a faint area of hypermetabolism in the midline of lower anterior abdominal wall with SUV up to 2.5. This corresponds to the infiltration of fat. The findings are likely due to mild inflammatory changes.

IMPRESSION:

1. Hypermetabolic middle mediastinal and left hilar nodes consistent with metastasis, new finding.
2. Bilateral retroperitoneal adenopathy as well as left sidewall pelvic adenopathy.
3. Elongated area of hypermetabolism anterior to the upper spleen and in the area of anterolateral aspect of lower left rib. Rib metastasis versus metastatic nodule anterior to the spleen. Please correlate findings with CT examination. If no abnormal findings are seen on the CT examination, then nuclear medicine bone scan or left rib radiographs are suggested.
4. There is a faint area of hypermetabolism in the midline of lower anterior abdominal wall with SUV up to 2.5. This corresponds to the infiltration of fat. The findings are likely due to mild inflammatory changes.

PHYSICIAN: [REDACTED]

[page 23 of 75]
Imaging Result Report

Patient: [REDACTED]
Patient phone: [REDACTED]
Location: [REDACTED]

Ordering Physician [REDACTED]

Sex: [REDACTED]
Patient Type: [REDACTED]
MR#: [REDACTED]
Account#: [REDACTED]
Physician phone: [REDACTED]
Physician fax: [REDACTED]

DOB: [REDACTED]

REF: [REDACTED]
ADM: [REDACTED]
ATT: [REDACTED]
CC: [REDACTED]
PCP: [REDACTED]

Final Result

Procedure(s) Performed:
CT ABDOMEN W CONTRAST

Exam Date: [REDACTED] +1973

Accession #: [REDACTED]

Diagnosis: [REDACTED]
Reason for Exam: [REDACTED]

+1244

+1976

D: [REDACTED]

T: [REDACTED]

CT OF THE ABDOMEN AND PELVIS WITH CONTRAST:

Indication: [REDACTED] with abdominal pain and history of colon carcinoma.

A 5 mm spiral CT scan of the abdomen and pelvis was obtained with oral and intravenous contrast infusion of 140 cc Optiray 320.

CT Abdomen:

At the lung bases, there are several small nodules ranging in size from 3-4 mm up to 1 cm in size, slightly more prominent from the exam of [REDACTED] suspicious for metastasis. There is linear atelectasis at the lung bases as well.

No focal abnormality is seen involving the liver, the spleen. There are bilateral adrenal nodules on the left measuring 1.1 cm in size, and on the right measuring 6-7 mm in size. These have not changed appreciably from the previous exam and are indeterminate.

The spleen is unremarkable. A splenule is present. The pancreas and gallbladder are unremarkable. Both kidneys function symmetrically with slight bilateral ectasia of both urinary tract collecting systems without calcified ureteral stone. There are borderline enlarged retroperitoneal lymph nodes. There is infiltration of mesenteric fat. In the mid abdomen anteriorly, the fluid collection previously described as 8 x 3 cm in size is now 3

[page 24 of 75]
[REDACTED]

x 1 cm in size, decreased, much improved.

CT Pelvis:

There is considerable induration of the lower anterior abdominal wall fat and near the anterior abdominal wall muscles. There is small fluid and infiltration of fat in the sacrococcygeal region. Surgical chains in the rectosigmoid colon are noted.

There is marked diffuse thickening of the urinary bladder wall measuring up to 1.1 cm in thickness, significantly increased, unfavorable from the exam of [REDACTED] +1944

There are degenerative changes of the lumbar spine.

IMPRESSION:

+1944
Since the exam of [REDACTED] the fluid collection immediately posterior to the anterior mid abdominal wall is now smaller, improved from the exam of [REDACTED] +1944

There are numerous small nodules at both lung bases suspicious for metastasis, with unfavorable change from the previous exam. There is minimal pleural thickening at the left lung base.

Bilateral indeterminate adrenal nodules without significant change.

Mildly dilated renal pelvis and ureters bilaterally, however, significance and etiology undetermined.

The urinary bladder is now diffusely markedly thickened, with the wall measuring slightly over 1.1 cm in thickness, unfavorable change, possible from medication or inflammatory in origin.

Inflammatory induration of lower anterior abdominal wall and abdominal wall muscles and presacrococcygeal induration of fat noted.

The small bowel loops are less dilated representing an improvement from the exam of [REDACTED] +1944

Interpreted by: [REDACTED]

[REDACTED]

Signed By: [REDACTED]

Released Date/Time: [REDACTED] +1976

Transcribed By:

[page 25 of 75]
Imaging Result Report

Patient: [REDACTED]
Patient phone: [REDACTED]
Location:

Ordering Physician: [REDACTED]

Sex: [REDACTED]
Patient Type:
MR#: [REDACTED]
Account#:
Physician phone:
Physician fax:

DOB: [REDACTED]

REF:
ADM:
ATT:
CC:
PCP:

Final Result

Procedure(s) Performed:
CT CHEST W CONTRAST

Exam Date: [REDACTED] +1955

Accession #: [REDACTED]

Diagnosis:

Reason for Exam: re- colon ca lung nodules seen on ct

[REDACTED] +1956
D: [REDACTED] T: [REDACTED]
CT THORAX, [REDACTED] +1955

Helical thoracic CT examination between the supraclavicular fossa and mid hepatic level was obtained with intravenous administration of 100 cc of nonionic iodinated contrast material (Optiray 320). Several 5 mm thin reformatted transverse images are available for interpretation.

Indication: Lung nodules and history of colon cancer.

The current examination is compared with the previous CT angio thorax dated [REDACTED] +1764

There is no abnormal mediastinal soft tissue mass or lymphadenopathy. There is no hilar lymphadenopathy.

Main pulmonary artery is mildly dilated measuring approximately 3.3 cm in size, sometimes seen in patients with pulmonary hypertension.

Thoracic aorta is normal in size. There is no abnormal pleural thickening or pleural calcification. Small amount of pleural fluid is noted in the posteroinferior aspect of the left hemithorax. There is no right pleural fluid collection.

The previously noted pulmonary opacities have resolved. However, the current examination demonstrates several new pulmonary nodules, suspicious for metastasis in both lungs. These are primarily

[page 26 of 75]
peripheral in location and measure between 2 to 10 mm in size, with relatively larger one in posterolateral aspect of the upper lobe of the left lung.

The approximately 4 to 5 mm sized low-density area in anterior aspect of the right lobe of the liver adjacent to the falciform ligament in image #69 series 2, represents focal fat infiltrate.

IMPRESSION:

CT thorax demonstrates:

Several 2 to 10 mm sized metastasis in both lungs, new when compared to previous examination (previously noted pulmonary nodules have resolved completely).

Small amount of left pleural fluid collection. There is complete resolution of previously noted right pleural fluid collection.

There is no mediastinal or hilar lymphadenopathy.

Approximately 4 to 5 mm sized focal fat infiltrate anterior aspect of the right lobe of the liver adjacent to the falciform ligament.

Approximately 10 to 12 mm sized probable adenoma of left adrenal gland, stable in its size.

Interpreted by:

+1956

[page 27 of 75]
PATIENT:
PATIENT PHONE
LOCATION:

SEX: DOB:
PATIENT TYPE:
MR#:
ACCOUNT#:

ORDERING PHYSICIAN:

REF:
ADM:
Att:
CON:
ORD:

EXAM D/T: +1894

CI#	Order	Exam
	0001	CT ABDOMEN WITH CONTRAST
	0002	CT PELVIS WITH CONTRAST

Ord Diag: 153.9-MALIGNANT NEO COLON NOS

Ord Diag: 153.9-MALIGNANT NEO COLON NOS

JOB v D: T:

+1894

+1895

CT STUDY OF THE ABDOMEN AND PELVIS, WITH CONTRAST INFUSION:

Indication: Metastatic colon carcinoma.

Comparison is made with patient's previous exam dated +1565

Images obtained through the lung bases show the lung bases to be well-aerated. There is a tiny nodule noted at the right lung base anteriorly measuring 5 mm in diameter. A similar-appearing very small nodule is seen at the left lung base measuring 6 mm in diameter. A third nodule adjacent to the pleura is noted measuring 2 mm in diameter. These are new when comparison is made with the previous exam.

The liver and spleen are normal in size. The density patterns are homogeneous. No significant pancreatic abnormality is noted. There is no adrenal lesion. The kidneys are symmetrical in size and shape with no evidence for a renal cortical mass or significant hydronephrosis. Surgical clips are seen within the retroperitoneum and within the mid anterior abdomen. There is an ostomy site within the right lower quadrant, unremarkable in its appearance. There is slightly increased density noted in a linear fashion within the midline consistent with a postsurgical defect.

Images obtained through the pelvis show mild presacroccygeal

FINAL

Page 1

[page 28 of 75]
RADIOLOGY REPORT

PATIENT: [REDACTED]
PATIENT PHONE #: [REDACTED]
LOCATION: DIS

ORDERING PHYSICIAN: [REDACTED]

SEX: [REDACTED] DOB: [REDACTED]
PATIENT TYPE: [REDACTED]
MR#: [REDACTED]
ACCOUNT#: [REDACTED]

REF: [REDACTED]
ADM: [REDACTED]
Att: [REDACTED]
CON: [REDACTED]
ORD: [REDACTED]

EXAM D/T: [REDACTED] +1894

Checkin-Exam Code Summary

fascial stranding and soft tissue fullness. The presacroccocygeal changes are new when comparison is made with the previous study.

IMPRESSION:

There are at least three small nodules noted at the lung bases, new when comparison is made with a previous study from [REDACTED] In ~+1565 view of the known history of colon carcinoma, these are suspicious for lung metastases.

No significant liver lesions are noted to suggest liver metastasis. No significant retroperitoneal lymphadenopathy is noted.

Unremarkable appearance noted to the right lower quadrant colostomy. There is prominent presacroccocygeal soft tissue stranding and fullness which can be postsurgical. However, the possibility of recurrent or residual neoplasm at this site is not entirely excluded.

Interpreted by: [REDACTED]

Transcribed By- [REDACTED]
Interpreted By- [REDACTED]
Released By- [REDACTED]
Released Date Time- [REDACTED] +1895

[page 29 of 75]
PATIENT: [REDACTED]
DATE OF BIRTH: [REDACTED]

PHYSICIAN: [REDACTED]

Date of Service: [REDACTED] +1889

PET WHOLE BODY, colon, restaging

RADIOPHARMACEUTICAL: 12.6 mCi F-18 fluorodeoxyglucose (FDG), IV, injected through right antecubital vein.

-365

+1761 CLINICAL: This is a [REDACTED] with a history of colon carcinoma diagnosed on [REDACTED]. Partial colonic resection was performed. There is a history of hysterectomy. The patient received radiation and chemotherapy which terminated on [REDACTED]. The examination is performed for restaging of the disease.

TECHNIQUE: Approximately 60 minutes after injection of the radiopharmaceutical, PET imaging from the base of the brain to the proximal thighs was performed with whole body attenuation-correction. Images were reconstructed into transaxial, coronal, and sagittal planes for interpretation.

+1706

FINDINGS: Comparison is made to the prior whole body PET scan of [REDACTED]. Provided previous PET scan - CT fusion report of [REDACTED] as well as CT chest, abdomen and pelvis report from [REDACTED] are reviewed. Mass at the top of the vaginal cuff was reported. Nodule lateral to the descending colon was reported as well. Additionally, 6 mm nodule in the superior segment of the right lower lobe was reported. +1812

In the present examination, no abnormal hypermetabolic lesion is seen in the expected superior segment of the right lower lobe. Please note that the nodule is small in size. There is no abnormal area of hypermetabolism in the expected location of the descending colon or in the vaginal cuff. Normal physiologic muscle uptake is present at the base of the neck as well as in the gluteal region, likely due to patient's clinical nervous status. There is a small area of hypermetabolism superior to the urinary bladder, seen best in the coronal images. The findings appear to represent bowel activity. SUV is up to 2.9.

IMPRESSION:

1. No abnormal area of hypermetabolism is present in the superior segment of the right lower lobe, in the vaginal cuff, or in the expected location of the descending colon.
2. Negative for metastatic disease.

PHYSICIAN: [REDACTED]

[page 30 of 75]
Imaging Result Report

Patient: [REDACTED]
Patient phone: [REDACTED]
Location: [REDACTED]

Ordering Physician [REDACTED]
[REDACTED]

Sex: [REDACTED]
Patient Type: [REDACTED]
MR#: [REDACTED]
Account#: [REDACTED]
Physician phone: [REDACTED]
Physician fax: [REDACTED]

DOB: [REDACTED]

REF: [REDACTED]
ADM: [REDACTED]
ATT: [REDACTED]
CC: [REDACTED]
PCP: [REDACTED]

Final Result

Procedure(s) Performed:
CT ABDOMEN W CONTRAST

Exam Date: [REDACTED] +2161

Accession #: [REDACTED]

Diagnosis: [REDACTED]
Reason for Exam: [REDACTED]

JOB # [REDACTED] D: [REDACTED] T: [REDACTED]
+2161 +2161

CT ABDOMEN AND PELVIS WITH CONTRAST:

Indication: [REDACTED] with a history of lower abdominal pain and diarrhea. The patient has a history of colon carcinoma.

Comparison studies: [REDACTED] +1973

Technique: The study was performed using 5 mm helically acquired axial images from the lung bases to the ischia following the intravenous administration of 140 cc of Optiray 320, nonionic contrast. Delayed images were obtained at the same levels.

Findings:

Screening images of the lung bases demonstrate no evidence of focal consolidation, pneumothorax or pleural effusion. There is mild cardiomegaly without evidence of pericardial effusion.

The liver a homogeneous parenchymal pattern and there is mild prominence of the intrahepatic biliary radicles. A fluid filled gallbladder is demonstrated. The pancreas and the spleen appear within normal limits.

There has been no significant interval change in the 2.0 cm x 1.3 cm left adrenal nodule likely representing a benign adrenal adenoma. There is no evidence of adrenal gland mass or enlargement of the right adrenal gland. The kidneys symmetrically excrete

[page 31 of 75]
[REDACTED]

contrast without evidence of obstruction. There is no evidence of significant upper retroperitoneal lymphadenopathy, free fluid or free air.

Contrast material is seen throughout the bowel, however the proximal small bowel is diffusely dilated with air-fluid levels measuring up to 4.6 cm in dilatation, up to the level of the mid abdominal anastomosis. Contrast is seen distally. An additional anastomosis is seen in the rectosigmoid region and there, again, is diffuse soft tissue thickening in the presacral region and perirectal region. Diffuse urinary bladder wall thickening is again demonstrated. No significant inguinal lymphadenopathy is demonstrated. Bone windows demonstrate degenerative changes of the thoracolumbar spine without evidence of gross lytic or blastic lesions.

IMPRESSION:

Proximal partial small bowel obstruction with dilated proximal small bowel loops with air-fluid levels, to the level of the anastomosis in the mid abdomen. Contrast is seen distally in the bowel.

Stable appearance of the left adrenal mass likely representing a benign adrenal adenoma.

Stable appearance of the presacral soft tissue thickening and perirectal soft tissue thickening.

Stable appearance of the urinary bladder wall thickening.

A preliminary report was issued immediately following the examination.

Interpreted by: [REDACTED]

Transcribed By [REDACTED]

Interpreted By [REDACTED]

Released By- [REDACTED]

Released Date [REDACTED]

+2161

Signed By: [REDACTED]

Released D [REDACTED]

Transcribed [REDACTED]

+2161

[page 32 of 75]
PATIENT: [REDACTED]
DATE OF BIRTH: [REDACTED]

PHYSICIAN: [REDACTED]

Date of Service [REDACTED] +2153

PET WHOLE BODY, colon, restaging;
receiving chemotherapy

RADIOPHARMACEUTICAL: 14.7 mCi F-18 fluorodeoxyglucose (FDG), IV, injected
through right antecubital vein.

-347

CLINICAL: This is a [REDACTED] with a history of colon carcinoma
diagnosed on [REDACTED]. The patient had a partial colon resection. Recently, colostomy was
removed. The patient received radiation treatment which ended on [REDACTED]. The patient is +1732
currently receiving chemotherapy every month. The examination is performed for restaging
of the disease.

TECHNIQUE: The patient's fasting blood glucose level was 131 mg/dl. Approximately 60
minutes after injection of the radiopharmaceutical, PET imaging from the base of the brain
to the proximal thighs was performed with whole body attenuation-correction. Images were
reconstructed into transaxial, coronal, and sagittal planes for interpretation.

+2006

FINDINGS: Comparison is made to the prior whole body PET scan of [REDACTED]. At that
time, metastatic mediastinal, hilar and retroperitoneal nodes were present. There was a left
pelvic mass and some bony lesions.

In the present examination, there is an excellent response to the chemotherapy with complete
regression of previously identified hilar and mediastinal nodes as well as regression of
retroperitoneal nodes and the left pelvic mass. Previously seen hypermetabolic lesion in
some of the left ribs are not present in the current study. Liver remains mildly enlarged. No
hypermetabolic lesion is noted in the liver. No abnormal tracer accumulation in the
distribution of colon.

IMPRESSION:

1. Interval excellent response to the chemotherapy with complete regression of
previously identified metastatic lesion in the mediastinum, hila, retroperitoneum and
bones.
2. Negative for metastatic disease in the current study.

PHYSICIAN: [REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[page 33 of 75]
Patient: [REDACTED]
Patient phone: [REDACTED]
Location: Presence [REDACTED]

Ordering Physician: [REDACTED]

Sex: [REDACTED]
Patient Type: [REDACTED]
MR#: [REDACTED]
Account#: [REDACTED]
Physician phone: [REDACTED]
Physician fax: [REDACTED]

DOB: [REDACTED]

REF: [REDACTED]
ADM: [REDACTED]
ATT: [REDACTED]
CC: [REDACTED]
PCP: [REDACTED]

Final Result

Procedure(s) Performed:
CT ABDOMEN & PELVIS W CONTRAST

Exam Date: [REDACTED]

Accession #: [REDACTED]

Diagnosis:
Reason for Exam: abd pain

POSTCONTRAST CT OF THE ABDOMEN AND PELVIS - [REDACTED] +4105

Indication: [REDACTED] with abdominal pain, history of colon carcinoma.

Comparison: [REDACTED]

+3917, +4105

Technique: Following oral contrast and during infusion of 100 mL of Optiray 320, 5 mm scans were obtained through the abdomen and pelvis. Delayed scans during the peak excretory phase were also obtained. Coronal and sagittal reconstructions were obtained.

Findings:

The liver is slightly elongated but is otherwise unremarkable, with no focal lesion. The gallbladder is globular in shape but not truly distended. No calcified stones are seen and there is no wall thickening or pericholecystic fluid. The appearance has not changed significantly. The common bile duct is mildly distended but tapers distally, and the findings are unchanged. The pancreas is relatively atrophic. The spleen and right adrenal are unremarkable. There is thickening of the apex of the left adrenal, unchanged since [REDACTED] and likely due to a small adenoma. Both kidneys demonstrate prompt symmetrical function and excretion and are without focal lesion. There is no hydronephrosis. Contrast does not extend into the urinary bladder, however. Mild wall thickening of the urinary bladder is nonspecific.

Stomach and small bowel loops are normal in overall appearance. There is a dilated small bowel loop in the midpelvis at site of anastomosis this is likely related to postoperative change and has not change significantly since previous CT. There is no wall thickening in the region. The patient has had a right hemicolectomy and the anastomosis is widely patent. The entire colon is mildly to moderately distended to the rectosigmoid anastomosis. There is wall thickening and narrowing at the anastomosis. There is also surrounding fluid and edema and presacral edema. No mass or lymphadenopathy is seen. Degenerative changes of the lower lumbar spine are present.

IMPRESSION:

[page 34 of 75]
[REDACTED]

There is marked narrowing and wall thickening at the rectosigmoid anastomosis with proximal colonic dilatation. There is also fluid and presacral edema in the region. The stricture may be due to fibrosis but recurrent neoplasm is considered.

There is marked focal dilatation of a small bowel loop at site of anastomosis, unchanged. Small bowel is otherwise unremarkable.

The gallbladder is globular in shape and there is mild dilatation of the common bile duct but it tapers distally, and the findings are unchanged, with no acute abnormality. There is mild wall thickening of the urinary bladder, nonspecific. The remainder of the examination is unremarkable.

A preliminary report was issued immediately following the examination.

Signed by [REDACTED] +4106

Signed By: [REDACTED]

Released Date/Time: [REDACTED]

Transcribed By: [REDACTED]

[page 35 of 75]
Patient: [REDACTED]
Patient phone: [REDACTED]
Location: Presence [REDACTED]

Ordering Physician: [REDACTED]

Sex: [REDACTED]
Patient Type: [REDACTED]
MR#: [REDACTED]
Account#: [REDACTED]
Physician phone: [REDACTED]
Physician fax: [REDACTED]

DOB: [REDACTED]

REF: [REDACTED]
ADM: [REDACTED]
ATT: [REDACTED]
CC: [REDACTED]
PCP: [REDACTED]

Final Result

Procedure(s) Performed:
CT ABDOMEN & PELVIS W CONTRAST

Exam Date: [REDACTED]

+3923

Diagnosis:

Reason for Exam: abd pain, hx of multiple surgeries

Accession #: [REDACTED]

CT OF THE ABDOMEN AND PELVIS WITH CONTRAST:

Compared to [REDACTED] +2807

Findings:

There is distention of small bowel loops seen to approximately the mid small bowel. The distal small bowel is decompressed. The findings are suspicious for a small bowel obstruction. There are surgical changes noted in the small bowel. The transition zone is likely in the lower abdomen anteriorly. A small amount of free fluid is seen in the anterior abdomen in the region of the suspected transition zone. There is some contrast seen in large bowel with some distention of the distal large bowel and focal thickening noted in the region of surgery at the rectal level. Presacral edema is noted.

There is no focal hepatic, splenic or right adrenal lesion. The left adrenal demonstrates thickening and a small nodule at the apex of the adrenal gland similar to that seen previously. There is mild prominence of the right renal pelvis, decreased compared to the previous exam. The left renal pelvis is no longer dilated.

IMPRESSION:

1. Findings suspicious for partial or early small bowel obstruction.
2. There is also some thickening of the distal large bowel in the region of the anastomosis with only mild large bowel dilatation noted.
3. Ascites noted in the region of the suspected small bowel transition point of obstruction.

Interpreted by: [REDACTED]

Job # [REDACTED] D: [REDACTED] T: [REDACTED]
+3924

Signed By: [REDACTED]

Released Date/Time: [REDACTED] +3926

Transcribed By: [REDACTED]

[page 36 of 75]
Imaging Result Report

Patient: [REDACTED]
Patient phone: [REDACTED]
Location: [REDACTED]

Ordering Physician [REDACTED]

Sex: [REDACTED]
Patient Type: [REDACTED]
MR#: [REDACTED]
Account#: [REDACTED]
Physician phone: [REDACTED]
Physician fax: [REDACTED]

REF: [REDACTED]
ADM: [REDACTED]
ATT: [REDACTED]
CC: [REDACTED]
PCP: [REDACTED]

Final Result

Procedure(s) Performed:
CT ABDOMEN W CONTRAST

Exam Date: [REDACTED] +2815

Accession #: [REDACTED]

Diagnosis:
Reason for Exam: diarrhea

CT OF THE ABDOMEN AND PELVIS:

Indication: Diarrhea.

Contiguous 5 mm transverse images were obtained through the abdomen and pelvis after the intravenous administration of 150 cc Optiray 320 as well as oral contrast. Comparison is made to prior CT of the abdomen from [REDACTED] +2161

There is a small left pleural effusion with a mild rim of adjacent parenchymal consolidation. Some minimal changes are noted at posterior right lung base. There is a 1.6 cm lesion in the body of the left adrenal gland which previously measured 1.4 cm. There is hydronephrosis on the left and a dilated left ureter can be traced to the urinary bladder where there is mild prominence of the wall of the bladder. The nephrograms appear symmetric. Right renal pelvis appears slightly more prominent than on the prior examination. There is presacral soft tissue density and postoperative changes in rectosigmoid colon region. Wall of the rectosigmoid region near the anastomosis appears mildly prominent. Wall of the colon in cecal region appears mildly prominent. There are postsurgical changes on both sides of the pelvis. An air bubble is noted on the left posterior and lateral to the rectosigmoid colon.

IMPRESSION:

Small left pleural effusion with mild rim of adjacent parenchymal consolidation.

[page 37 of 75]
1.6 cm left adrenal nodule appears slightly more prominent when compared to study of [REDACTED] +2161

Mild hydronephrosis on the left and mild prominence of the right renal pelvis are new since the prior study and there is questionable thickening of the wall of the urinary bladder on the left posteriorly and laterally. Small lesion cannot be excluded and clinical correlation is advised with further evaluation as warranted.

Questionable bowel wall thickening involving right colon in the lower quadrant of the abdomen near a surgical anastomosis may relate to nondistention.

Postsurgical changes in rectosigmoid region with persistent soft tissue density changes in the presacral space, however, there does appear to be a new extraluminal air bubble in this region raising question of a perforation or fistula. In addition, wall of the rectosigmoid colon appears prominent, and I am uncertain whether this relates to prior surgery or an acute process. Clinical correlation is advised.

Interpreted by [REDACTED]

Job # [REDACTED] d. [REDACTED] t. [REDACTED] +2815

Interpreted By [REDACTED]

Transcribed By [REDACTED]

Released By- [REDACTED]

Released Date Time- [REDACTED]

Signed By: [REDACTED]

Released Date/Time: [REDACTED] +2815

Transcribed By: [REDACTED]

[page 38 of 75]
Patient: [REDACTED]
DOB: [REDACTED] Age: [REDACTED] Sex: [REDACTED]

CEA

[page 39 of 75]
Pat. Name	Adm. Date	Sex	Age	Location	Allergies	Relationship	Adm. Diagnosis
(+) [REDACTED]	[REDACTED] +3699	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Go to...

Report for [REDACTED], [REDACTED] (MRN: [REDACTED])

TEST: CEA

Collected Date & Time: [REDACTED] +3699

Result Name	Results	Units	Reference Range
CEA	5.2 H	ng/mL	0.0-3.8

(NOTE)

This test result should not be interpreted as absolute evidence of the presence or absence of malignant disease. Smoker may have values up to 5.5 ng/mL.

Performed at [REDACTED]

[page 40 of 75]
Pat. Name	Adm. Date	Sex	Age	Location	Allergies	Relationship	Adm. Diagnosis
⊕ [REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]
	+3699						

Go to...

Report for [REDACTED], [REDACTED] (MRN: [REDACTED])

TEST: CEA

Collected Date & Time: [REDACTED] +3540

Result Name	Results	Units	Reference Range
CEA	3.9 H	ng/mL	0.0-3.8
3.9			

(NOTE)

This test was performed using the Roche

Elecys Electrochemiluminescent Method.

Values obtained with different assay methods cannot be used interchangeably.

This test result should not be interpreted

as absolute evidence of the presence or absence of malignant disease.

Smoker may have values up to 5.5 ng/mL.

Performed at [REDACTED]

[page 41 of 75]
	Pat. Name	Adm. Date	Sex	Age	Location	Allergies	Relationship	Adm. Diagnosis
⊕	[REDACTED] [REDACTED]	[REDACTED] +3699	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]		[REDACTED]

Go to...

Report for [REDACTED] (MRN: [REDACTED])

TEST: CEA

Collected Date & Time: [REDACTED] +2850

Result Name	Results	Units	Reference Range
CEA	3.8(..)	ng/mL	0.0-3.8
3.8			
Performed at	[REDACTED]		

[page 42 of 75]
Pat. Name	Adm. Date	Sex	Age	Location	Allergies	Relationship	Adm. Diagnosis
⊕ [REDACTED]	[REDACTED] +3699	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Go to...

Report for [REDACTED] (MRN: [REDACTED])

TEST: CEA

Collected Date & Time [REDACTED] +2763

Result Name	Results	Units	Reference Range
CEA	5.2 H	ng/mL	0.0-3.8

Smoker may have values up to 5.5 ng/mL

Performed at [REDACTED]

[page 43 of 75]
⊕	Pat. Name	Adm. Date	Sex	Age	Location	Allergies	Relationship	Adm. Diagnosis
	[REDACTED]	[REDACTED] +3699	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Go to...

Report for [REDACTED] (MRN: [REDACTED])

TEST: CEA

Collected Date & Time: [REDACTED] +2740

Result Name	Results	Units	Reference Range
CEA	2.8(.,)	ng/mL	0.0-3.8
Performed	[REDACTED]		

[page 44 of 75]
Result Trend Report

Printed: [REDACTED]

Patient: [REDACTED]

Date/Time	CEA	CEA
[REDACTED] +2594	2.8	
[REDACTED] +2552	5.3 H	
[REDACTED] +2512	11.6 H	
[REDACTED] +2510	11.1 H (0-4.7)	
[REDACTED] +2426		1.5 (0-2.5)
[REDACTED] +2398		1.7
[REDACTED] +2342		1.4
[REDACTED] +2272		1.4
[REDACTED] +2244		1.6
[REDACTED] +2230		1.3
[REDACTED] +2188		1.2
[REDACTED] +2159		0.9
[REDACTED] +2118		0.9
[REDACTED] +2076		3.2 H
[REDACTED] +2041		23.8 H
[REDACTED] +2022		90.7 H
[REDACTED] +1987		184.1 H
[REDACTED] +1873		23.6 H (normal range 0-2.5)

[page 45 of 75]
Pat. Name	Adm. Date	Sex	Age	Location	Allergies	Relationship	Adm. Diagnosis
⊕ [REDACTED]	[REDACTED] +3699	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Go to...

Report for [REDACTED], [REDACTED] (MRN: [REDACTED])

TEST: CEA

Collected Date & Time: [REDACTED] 1947

Result Name	Results	Units	Reference Range
CEA	96.2 H	ng/mL	<5.2

[page 46 of 75]
[Redacted]

CEA results

[Redacted]

+1596	11.2	0-2.5
+1623	19.2	0-2.5
+1704	68.8	0-2.5
+1764	36	0-2.5
+1873	23.6	0-2.5

*CEA's from patient's medical
record*

[Redacted]

[page 47 of 75]
CEA results

+795	5.5	0-2.5
+816	4.7	0-2.5
+847	4.9	0-2.5
+879	5	0-2.5
+914	4.4	0-2.5
+955	3	0-2.5
+994	3.1	0-2.5
+1060	7.3	0-2.5
+1126	19.5	0-2.5
+1204	210.5	< 5
+1218	166	0-2.5
+1243	176.9	0-2.5
+1270	253.3	0-2.5
+1291	86.8	0-2.5
+1305	39.6	0-2.5
+1319	20.9	0-2.5
+1375	7.8	0-2.5
+1425	6.2	0-2.5
+1453	5.4	0-2.5
+1481	4.9	0-2.5
+1502	6.6	0-2.5
+1516	6.7	0-2.5
+1544	7.1	0-2.5
+1572	7.5	0-2.5

[page 48 of 75]
CEA results

DATE	CEA	RANGE
+24	14.4	0-4.5
+120	2.6	0-3
+161	2.6	0-3
+216	2.1	<5
+234	2.4	0-3
+297	2.1	0-3
+363	2.2	0-3
+441	10.6	0-2.5
+455	13.1	0-2.5
+481	25.8	0-2.5
+509	31.8	0-2.5
+522	49.4	0-2.5
+550	67.9	0-2.5
+560	69	0-2.5
+584	56.3	0-2.5
+627	16	0-2.5
+669	6.3	0-2.5
+697	7.3	< 2.5
+711	8.3	0-2.5
+732	8	0-2.5
+753	9.1	0-2.5
+774	8.8	0-2.5

[page 49 of 75]
MR [REDACTED]

+4456

Result Narrative

+4456

Patient Name: [REDACTED]

Procedure Date: [REDACTED]

MRN: [REDACTED]

Account Number: [REDACTED]

Date of Birth: [REDACTED]

Admit Type: [REDACTED]

Age: [REDACTED]

Room: [REDACTED]

Gender: [REDACTED]

Providers: [REDACTED]

Procedure:

Colonoscopy with forceps biopsies

Pre OP Indications:

Hematochezia, Anemia, Diarrhea, H/O colon cancer surgery and small bowel resections.

Referring MD: [REDACTED]

Medicines:

Monitored Anesthesia Care

Complications:

No immediate complications.

Procedure:

After I obtained informed consent, the scope was passed under direct vision. Throughout the procedure, the patient's blood pressure, pulse, and oxygen saturations were monitored continuously. The colonoscope was introduced through the anus and advanced to the ileocolonic anastomosis. The colonoscopy was performed without difficulty. The patient tolerated the procedure well. The quality of the bowel preparation was good.

Post OP Findings:

There was evidence of a prior end-to-end ileo-colonic anastomosis in the ascending colon at 70cm from the anal verge. This was patent. This was characterized by healthy appearing mucosa. This was traversed. Biopsies were taken of the small intestine with a cold forceps for histology.

Normal mucosa was found in the descending colon, in the transverse colon and in the ascending colon. Random biopsies were taken with a cold forceps for evaluation of microscopic colitis.

There was evidence of a prior end-to-side colo-rectal anastomosis in the sigmoid colon at 10 cm from the anal verge. This was patent. This was characterized by healthy appearing mucosa. This was traversed.

Non-bleeding external and internal hemorrhoids were found during perianal exam and during endoscopy and were mild- moderate with erythema.

Impression:

- Patent end-to-end ileo-colonic anastomosis. Biopsied.
- Normal mucosa in the descending colon, in the transverse colon and in the ascending colon. Biopsied.
- Patent end-to-side colo-rectal anastomosis.
- Non-bleeding external and internal hemorrhoids.
- No old blood or active bleeding sites visualized.

Recommendation:

- Await pathology results.

Pg 1 of 2

[page 50 of 75]
- [REDACTED]
- [REDACTED]
- Resume Coumadin (warfarin) at prior dose. Refer to managing physician for further adjustment of therapy.
- Regular to soft diet.

[REDACTED] +4456

This report has been signed electronically.
Number of Addenda: 0

Note Initiated On: [REDACTED] +4456
CC Letter to:

Linked Documents

[View Image](#)

Lab and Collection

COLONOSCOPY on [REDACTED] +4456

Encounter

[View Encounter](#)

Result Information

Status
Final result ([REDACTED]) +4456
Provider Status: Ordered

Lab Information

Encounter-Level Documents

PACS Images

Show images for COLONOSCOPY

COLONOSCOPY (Order

Procedures

Order: [REDACTED]

Released By: Auto-released
Authorizing: [REDACTED]
MD

Date: [REDACTED] +4456
Department: [REDACTED]

Order History

Inpatient

	Date/Time	Action Taken	User	Additional Information
+4456	[REDACTED]	Release		From Order: [REDACTED]
+4456	[REDACTED]	Result	[REDACTED]	Final

Order Information

[page 51 of 75]
Patient:

Page 1 of 3

Click icon to view images for patient.

Pat. Name	Adm. Date	Sex	Age	Location	Relationship	Allergies	Adm. Diagnosis
(+) 	 +2762					CLOMIPHENE, Clomid	(153.9) MALIGNANT NEO COLON NOS, AFIB W RVR

Go to...

Report for (MRN:)TEST: Op ReportCollected Date & Time: +2731

Result Name	Results	Units	Reference Range
Op Report			

OPERATIVE REPORT

NAME:		DOB:	
PAT. LOC:		PAT. TYPE:	IP
ADMIT:	 +2730	DISCHARGE:	

DATE OF OPERATION: +2730

SURGEON:

ASSISTANT:

PREOPERATIVE DIAGNOSIS: SMALL BOWEL OBSTRUCTION.

POSTOPERATIVE DIAGNOSIS: SMALL BOWEL OBSTRUCTION SECONDARY TO INTENSE INTRAABDOMINAL ADHESION.

OPERATION: EXPLORATORY LAPAROTOMY, EXTENSIVE LYSIS OF ADHESIONS, CLOSURE OF ENTEROTOMY TIMES TWO AND ENTEROENTERIC ILEOCOLONIC ANASTOMOSIS.

ANESTHESIA: GENERAL.

ESTIMATED BLOOD LOSS: 200 CC.

DRAIN: ONE JACKSON-PRATT DRAIN LEFT IN THE PELVIC AREA.

INDICATIONS: This is a with an extensive medical history. She had a history of ovarian cancer, radical hysterectomy with radiation. She also had metastatic disease to the rectum which was removed with a low anterior resection. Subsequently, the patient developed anastomotic leakage and required a diverting stoma. She has also had another laparotomy for extensive adhesions and bowel obstruction and she has been presenting for the last one year now with intermittent complete

[page 52 of 75]
bowel obstruction. The patient has had an extensive workup. She is still on Avastin medication for chemotherapy which has now been held for six weeks. Her diet lately has been consisting mostly of liquids because otherwise she is really not able to tolerate any p.o. We did a small bowel series which shows a complete stricture in the area of the mid small bowel and after extensive recommendations by myself and her primary care physician and oncology the patient is now agreeable for an exploratory laparotomy. I did discuss with her in detail in the office all risks and benefits of the procedure, the risk of bleeding, the risk of infection, risk of possibly a permanent stoma, risk of reoperation, abscess formation, bowel injury, possible bowel resection, and she fully agrees and consents for the procedure. Other risks were also explained, the risk of MI, PE, DVT and she is aware of everything. She was unable to be given a bowel prep. Her last episode was a few days ago. For this reason she was just brought in with no bowel preparation.

PROCEDURE: The abdomen was prepped and draped sterilely. She had bilateral SCD as well as a Foley catheter. At this point of the procedure the abdomen was prepped and draped sterilely. A gram of Mefoxin was given and the same midline incision was used. We actually had to extend the incision up towards the xiphoid process in order to free up the adhesions in the entire abdominal cavity. Most adhesions were noted in the pelvic area but there were extensive adhesions throughout. The majority of the surgery was extensive adhesiolysis. During adhesiolysis there was one loop of bowel that was frozen into the pelvis and we were unable to mobilize it. Every attempt to mobilize this loop, I caused to enterotomies which were repaired immediately in two layers with interrupted 3-0 Vicryl suture and interrupted Lembert 3-0 silk sutures. After attempts to free this loop up in the pelvis were unsuccessful my fear was that I would cause more small bowel injury. We measured the length of bowel from the ligament of Treitz down to the area of the blockage in the pelvis and it measures approximately 140 cm of small bowel. I can see the terminal ileum entering the cecum but I cannot mobilize it whatsoever. For this reason at this point of the procedure my thoughts were either to do a stoma or proceed with an internal bypass and I decided to do an internal bypass. The internal bypass was done in a side-to-side fashion from the area of the mid ileum to the cecum. There was no appendix left behind. This was done in an antimesenteric fashion with the GIA 75 stapling device and then a TA 60 stapling device. The angles were oversewn with interrupted 3-0 silk sutures to take away tension. Also at the angle of the anastomosis as well. The anastomosis was tested and easily dilates with no evidence of any bleeding or any evidence of any bile spillage. At this point of the procedure all gloves were changed and we irrigated the bowel and cavity with about 4 liters of warm normal saline. After all the irrigant fluid was returned the bowel was run again from the ligament of Treitz all the way to the internal bypass anastomosis. It was completely intact. There was no evidence of any obstruction to this level. We rechecked the area of the enterotomies and those were intact. There was no bleeding or bile staining noted. a JP drain was left in the pelvis above the enterotomies through a stab incision in the left lower quadrant secured with a 3-0 nylon suture. The bowel was placed back in its normal anatomic position. There was no bleeding noted in the abdominal cavity. A Seprafilm was used over the bowel and then the fascia was closed with a running locked No. 1 PDS suture times two, each separately tied in the midline. Copious irrigation of the wound was used and then the skin was closed with staples. 4 x 4's, ABD and tape were applied. Blood loss was less than 200 cc. She was in stable condition postprocedure and will transfer to the SICU. Postoperatively, I anticipate a prolonged ileus. Will start her on TPN tomorrow.

[page 53 of 75]
Patient:

[REDACTED]

Job#:

PAT/ch1

[REDACTED]

cc: [REDACTED]

+2730

[page 54 of 75]
Report for

TEST: [REDACTED] Op Report

Collected Date & Time: [REDACTED] +2470

Result Name

Results

Units

Reference Range

[REDACTED] Op Report

OPERATIVE REPORT

NAME:

PAT. LOC:

ADMIT:

DOB:

PAT. TYPE:

DISCHARGE:

+2469

+2469

DATE OF OPERATION:

+2469

SURGEON:

PREOPERATIVE DIAGNOSIS:

HISTORY OF COLON CANCER AND CRAMPY ABDOMINAL PAIN.

POSTOPERATIVE DIAGNOSIS:

WELL HEALED ANASTOMOSIS AT 10 CM WITH NO EVIDENCE OF RECURRENCE AND GRADE 1 INTERNAL HEMORRHOIDS.

OPERATION:

COLONOSCOPY WITH BIOPSY.

ANESTHESIA:

IV SEDATION.

INDICATION:

This is a [REDACTED] with a history of both ovarian and colon cancer. The patient underwent TAH-BSO as well as a sigmoid colon resection many years ago. Her last colonoscopy was about three years ago. She has been having crampy abdominal pain and was referred to me for followup endoscopy. All risks and benefits were explained for the colonoscopy, risk of bleeding, infection, perforation. She fully agrees and consents for the procedure. She was given a MiraLax prep as an outpatient which she tolerated pretty well. She did say with the prep she had some cramping but she evacuated nicely.

PROCEDURE:

Once in the endoscopy suite she was placed in the left lateral decubitus position. IV sedation was given while the patient was being monitored. A pediatric colonoscope was used. It was entered into the anus and advanced gently all the way to the cecum. The cecum was identified by the ileocecal valve and the appendiceal orifice. The prep was very good actually. The cecum, ascending, transverse and descending colon were all within normal limits. I saw no evidence of any tumors, polyps or masses. There was a well-healed anastomosis in a circular fashion at the 10 cm mark. Biopsies were taken of the anastomosis itself. In the rectum there are some small grade 1 internal hemorrhoids but no obvious other findings. The scope was withdrawn. She tolerated the procedure well. Will await the biopsy results.

[page 56 of 75]
Age in years: [REDACTED]

Location: [REDACTED]

Date of Birth: [REDACTED]

Gender: [REDACTED]

Surgical Reports

SURGICAL REPORTS

PREOP DIAGNOSIS: RECURRENT RECTAL CARCINOMA.
PREOP INDICATION: RECURRENT COLORECTAL CANCER (DICTATED BY [REDACTED])
TREAT SYMPTOMS.

Date of Surgery: [REDACTED] +1823

Surgeon: [REDACTED]

Assistant: [REDACTED]

Location: [REDACTED] Bldg: [REDACTED]

PostOp Diagnosis: Recurrent rectal cancer (Dictated by [REDACTED])
Procedure: > 1. Abdominal exploration (Dictated by [REDACTED])
2. Lysis of adhesions for one hour.
3. En bloc resection of rectum with upper vagina.
4. Primary anastomosis.
5. Mobilization of the splenic flexure.
6. Proctoscopy.
7. Diverting loop ileostomy.
8. Intraoperative radiation therapy (Dictated by [REDACTED])
9. Cystoscopy (Dictated by [REDACTED])
10. Bilateral ureteral stent placement.
11. Intraoperative consultation.
12. Partial vaginectomy.

Drainage: 1 Foley Catheter, 2 Jackson-Pratt Drains

After the patient had been induced into anesthesia, she was placed in the combined position with all pressure points appropriately padded. Dr. [REDACTED] Team then came in and placed preoperative ureteral stents... Dictated by [REDACTED]

We were asked for stents preoperatively for a planned colon resection. The patient was placed in the dorsal lithotomy position and under general endotracheal anesthesia underwent panendoscopy using a 22-French cystoscope using the 0-, 30-, and 70-degree lenses. The urethra was normal. Both ureteral orifices were normal in configuration and appearance. Bladder mucosa throughout entirely unremarkable. The bladder moved well also without any evidence of mass effect. Then, 5-French whistle-tip catheters were placed up both ureteral orifices and secured in place with an 18-French Foley catheter and tied with heavy silk to this and placed to separate drainage bags. The patient tolerated this portion of the procedure without difficulty.

As the case proceeded, [REDACTED] called me back into the operating room. Because of the previous radiation therapy, we were unable to feel either of the stents intraoperatively, and the tumor mass was clearly adherent to the vaginal vault. There was question as to whether or not it was invading the base of the bladder. Using an EEA sizer, we were able to direct the vagina posteriorly as well as laterally in order to gain access to the vesicovaginal plane and then were able to dissect the upper portion of the vagina away from the bladder itself. The bladder was uninjured at the completion of this resection. We were able to palpate both of the ureteral stents. They were also intact and out of the surgical field.

The stents will be treated post-operatively per usual, and I am happy to

[page 57 of 75]
+1873

(Continued)

+1823

see the patient should he require. I thank him very much for his consultation... Dictated by [REDACTED]

After [REDACTED]'s Service had placed the preoperative ureteral stents, the patient was repositioned and prepped and draped, both the abdomen and the perineum in standard fashion. The patient's prior midline incision was completely removed, and the abdomen was entered in the upper abdomen through the upper aspect of her previous incision. We then dissected down and opened the entire incision without injury to the underlying bowel. Once we had done that, there were very few adhesions to the anterior abdominal wall. There were diffuse interloop adhesions of the small bowel and multiple adhesions to the side walls. We then spent the next hour to hour and 15 minutes taking down the adhesions. Eventually, we had the entire small bowel freed up. We then placed our retraction and began our exploration of the abdomen. Once both lobes of the liver were palpated and there was no evidence of metastatic disease, both diaphragms, the anterior wall of the stomach, the spleen, the pelvic sidewall, the anterior abdominal wall, and the small bowel were all without evidence of metastatic disease. Once this was done, we then placed our appropriate retraction and explored the pelvis. There was a focal area of thickening consistent with carcinoma between the anterior rectal wall, the top of the vagina, and the lower portion of the bladder. We first mobilized the left colon, taking down the splenic flexure. This allowed us then to divide the colon just above what appeared to be her previous anastomosis. We then divided the mesentery and entered into the presacral space without any difficulty. We then dissected posteriorly all the way down to approximately 4 cm from the pelvic floor and then became anterior. At this point in time, it was very difficult to determine where the trigone and the bladder were relative to this mass, and I asked Dr. [REDACTED] to scrub back in and help identify the anatomy of the bladder and ureters as they entered into the trigone. Once we had done that, we were able to then dissect the upper aspect of the vaginal cuff completely free from the bladder and carried this down all the way to the top of the rectum. Once we had divided the vagina and the specimen, we isolated the rectal tube distal to this and divided the rectum with a single firing of the TA50 thick tissue stapler. The specimen was sent off the field. I personally took it to Pathology and oriented them in regards to the specimen. They called back in and said a portion of the vaginal cuff was positive for microscopic adenocarcinoma. We then took another complete circumferential portion of the vagina basically down to the lower third of the vagina and sent this off for pathologic evaluation. They said the margins were all negative. We also sent any residual tissue in the area that had been close to the left side as redo margins, and these all came back negative. At this point in time, Dr. [REDACTED] scrubbed in and performed his IORT... Dictated by Dr. [REDACTED]

Following resection of the vaginal recurrence by Dr. [REDACTED] the specimen was evaluated in the Pathology Laboratory as well as an evaluation of the tumor bed. The initial margin was positive radially on the left side. Additional submitted tissue was negative for tumor. There was no gross residual disease remaining. There was an area on the left pelvic sidewall that was slightly roughened. It was close to the area that had the initial positive margin. It was elected to treat this area with intraoperative radiation therapy. The left pelvic sidewall vessels and nerves were within the IORT field as was the ureter. A 6.5-cm circular applicator with a 30-degree bevel was selected and placed into the pelvis and angled toward the left sidewall. Six sheets of lead were placed in the inferior pelvis to block the remaining rectum. The applicator was secured in position with the Bookwalter retractor, and the patient was docked to the linear accelerator. She received 1000 cGy with 9 MeV electrons to the 90% isodose depth. Following the completion of radiation, the patient was undocked from the accelerator. The applicator was removed, and the lead was removed. The surgical team then continued with the operation... Dictated by Dr. [REDACTED]

After the intraoperative radiation therapy was completed, I scrubbed back in with my service, and we performed our low rectal anastomosis with a 29-mm circular stapler. Both donuts were intact. Proctoscope was performed which showed good distention of the bowel proximal to the

[page 58 of 75]
HISTORICAL PATHOLOGY REPORTS

Terminal ID: [REDACTED] Run Date/Time: [REDACTED] +1873
Reporting period: [REDACTED]

+1823 [REDACTED] (Continued)

anastomosis without evidence of compromise. I then sewed the vagina cuff closed. This was leaving the vagina approximately 1.5 cm deep. Dr. [REDACTED] then scrubbed back in and re-inspected the bladder and the ureters and found that there was no evidence of injury. We placed two No. 19 Jackson-Pratt drains in the deep pelvis behind the rectal anastomosis, secured them to the skin with 3-0 nylon. We then constructed our ileostomy site in the right lower quadrant and identified the terminal ileum that we would bring up as our ileostomy. We then placed multiple sheets of Seprafilm underneath the incision after irrigating and then closed the primary incision with interrupted No. 1 Vicryls. The skin was closed with 3-0 Monocryl. The stoma was matured with interrupted 3-0 Vicryls. Patient tolerated the procedure well and was taken to the recovery area in stable condition... Dictated by Dr. [REDACTED]

Wound Type: TYPE II - CLEAN-CONTAMINATED

Transcriptionist: [REDACTED]

Electronically Signed: [REDACTED]

PATHOLOGY REPORTS

Pathology Reports

+1823

Surgical Pathology [REDACTED]

Requested By: [REDACTED]

Additional Physician: [REDACTED]

TISSUE DESCRIPTION:

A1 A2 A3 A4 A5 A6 A7 A8 A9 B1 B2 B3 B4 B5 C1 C2 C3 D1 E1
18.0 cm segment of rectosigmoid with portion of vagina (3.5 x 3.2 cm), tissue from the left pelvic sidewall margin (2.6 x 2.5 x 1.5 cm), revision of the left vaginal margin (5.5 x 2.4 x 1.1 cm), tissue from the rectal mesentery (5.8 x 2.0 x 0.5 cm), and tissue from the left bladder edge (1.6 x 1.0 x 0.3 cm).

DIAGNOSIS:

Rectosigmoid and vagina, resection: Residual/recurrent invasive grade 3 (of 4) rectal adenocarcinoma forming a 2.8 x 2.2 x 1.5 cm mass in the anterior rectal soft tissue with extension into the vaginal sidewall. The vaginal and colonic mucosa are free of tumor. The radial (soft tissue) margin is positive for adenocarcinoma. The vaginal and colonic margins are negative for tumor. Multiple (10) regional lymph nodes are negative for tumor.

Soft tissue, left pelvic sidewall margin, biopsy: Negative for tumor.

Vaginal margin, revision: Benign squamous mucosa and fibromuscular tissue, no tumor present.

Rectum, mesentery, biopsy: Adipose tissue with hemorrhage. No tumor present [REDACTED]

Bladder, left edge, biopsy: Benign fibroadipose tissue, no tumor present [REDACTED]

Electronically signed by [REDACTED]

+1823

[page 59 of 75]
Report ID: SURGICAL/PATHOLOGY REPORTS

Terminal ID: Run Date/Time:

Reporting period =

+1873

Results Summary

Page 4 (last)

+1705

Path Review of Outside Specimen ()

Referring Physician:

Requested By:

DIAGNOSIS:

+1665

Vaginal cuff, biopsy () Involved by grade 3 (of
4) adenocarcinoma, morphologically consistent with colorectal
primary. +1706

Electronically signed by

+1706

SPECIMEN DESCRIPTION:

A: Clinic Consult Material

TISSUE DESCRIPTION:

MATERIAL RECEIVED:

vaginal biopsy - 1 slide

SLIDE DISPOSITION:

1 slide returned

+1713

*** End of data ***

[page 60 of 75]
© 2006 The Authors
Journal compilation © 2006 Blackwell Publishing Ltd

□

1. **Introduction**

CARCINOMA OF

LEFT COI

[REDACTED] [REDACTED] [REDACTED] [REDACTED]

114

[page 61 of 75]
PROCEDURE CONTINUED:

Retrograde examination confirmed an intact mucosal surface of the right and transverse colons. There were no tumor masses, polyps, or ulcerations noted. No evidence of any active bleeding. The endoscope was brought down the descending and sigmoid colons to the level of the rectum where the endoscope was retroflexed 180° visualizing hemorrhoids. The endoscope was returned to the straight position and withdrawn. The patient tolerated the procedure well without incident and was placed in the postendoscopy recovery room for a period of observation before being discharged.

DISCUSSION: The patient was informed of the findings.
No recurrent carcinomas were noted in the colon.

+1278

JOB NO. :

d.

t.

CC:

OPERATIVE REPORT

[page 62 of 75]
[REDACTED]

DATE OF OPERATION:

[REDACTED] +524

SURGEON:

PREOPERATIVE DIAGNOSIS:

1. RULE OUT RECURRENT CARCINOMA OF THE COLON

POSTOPERATIVE DIAGNOSIS:

1. NORMAL COLONOSCOPY
2. HEMORRHOIDS

OPERATION:

1. TOTAL COLONOSCOPY
2. TERMINAL ILEOSCOPY
3. BIOPSY ILEOCECAL VALVE
4. BIOPSY TERMINAL ILEUM

INDICATIONS:

This [REDACTED] returns for evaluation of her colon. Originally, she had presented with a pelvic mass and a gynecologic evaluation was undertaken. CT scan confirmed the presence of an adnexal mass. Exploration confirmed the presence of a carcinoma of the sigmoid extending to the gynecologic structures. She successfully underwent a resection at another institution and was followed here for adjuvant chemotherapy. Recently, she was found to have a rising CEA level. PET scan was done in the past and is to be repeated.

BOWEL PREP:

Very good.

CONSCIOUS SEDATION:

(1) Fentanyl 100 mcg. (2) Versed 5 mg.

PROCEDURE:

After obtaining informed consent, the patient was placed in the left lateral decubitus position. Oxygen was administered via nasal prongs and noninvasive monitoring devices including a pulse oximeter, blood pressure cuff and EKG monitor were applied.

The patient was administered conscious sedation. Digital rectal examination confirmed a normal sphincter tone without masses in the rectal ampulla.

An Olympus PCF 160 video colonoscope was introduced through the anorectum and, under video monitoring, was passed proximally without any difficulty to the level of the ileocecal valve. A localized area of inflammation was identified on the valve and biopsies were taken and submitted to surgical pathology. The endoscope was gradually and carefully manipulated, entering into the terminal ileum. The mucosal surface appeared grossly normal.

CONTINUED

[REDACTED]

[REDACTED]

OPERATIVE REPORT

[page 63 of 75]
[REDACTED]

PAGE 2

PROCEDURE CONTINUED:

Retrograde examination confirmed an intact mucosal surface throughout the entire visualized colon. An occasional diverticulum was seen, particularly on the left side. There were no masses or polyps seen nor any evidence of bleeding. The endoscope was brought down to the ampulla and retroflexed 180 degrees, visualizing hemorrhoids. The endoscope was returned to the straight position and withdrawn. The patient tolerated the procedure well and without incident, was placed in the postendoscopy recovery room for a period of observation before being discharged.

DISCUSSION: The [REDACTED] were informed of the findings. No abnormalities were encountered at this time. Followup evaluation with [REDACTED] is indicated. A PET scan is scheduled in approximately three weeks. Further discussion regarding additional therapy will be pending the results of the PET scan.

[REDACTED] +524 +524
JOB NO.: [REDACTED] d. [REDACTED] t. [REDACTED]
CC: [REDACTED]

[REDACTED]

[REDACTED] [REDACTED] [REDACTED]
[REDACTED] OPERATIVE REPORT

[page 64 of 75]
PT. NAME: [REDACTED]

SEX/DOB: [REDACTED]

PT. HOME PHONE #: [REDACTED]

PT. TYPE: [REDACTED]

LOCATION: [REDACTED]

UNIT #: [REDACTED]

ORDERING PHYSICIAN: [REDACTED]

ACCOUNT #: [REDACTED]

ORDERING MD ADDRESS: [REDACTED]

ATTENDING PHYSICIAN: [REDACTED]

REFERRING PHYSICIAN: [REDACTED]

CONSULTING PHYSICIAN: [REDACTED]

ORDERING MD PHONE: ([REDACTED])

	CI #	CI DATE/TIME	EXAM CODE/DESCRIPTION
+518	[REDACTED]	[REDACTED]	CT BIOPSY GUIDANCE
	Ord Diag:	153.9-MALIGNANT NEO COLON NOS	
+518	[REDACTED]	[REDACTED]	CT CONSCUS SED-IV-IM-IH PER 1/2HR
+518	Ord Diag:	453.9-VENOUS THROMBOSIS NOS	
	[REDACTED]	[REDACTED]	IC PERITONEO/PARACENTESIS INIT
	Ord Diag:	PELVIC FLUID ASPIRATION	

+518

+519

JOB# [REDACTED] D: [REDACTED] T: [REDACTED]

CT-GUIDED PELVIC FLUID ASPIRATION UTILIZING INTRAVENOUS CONSCIOUS SEDATION:

Indication: Metastatic colon carcinoma.

+453

+509

Comparison is made with the patient's [REDACTED] and [REDACTED] CT scans of the abdomen and pelvis.

The CT-guided pelvic fluid aspiration procedure was performed with conscious sedation utilizing 1 mg of Versed and 50 mcg of fentanyl administered intravenously with constant monitoring of the patient throughout the entire procedure.

After informed consent was obtained, the patient was placed in the prone position upon the computed tomography examination table.

RADIOLOGY REPORT

[page 65 of 75]
PT. NAME: [REDACTED]

SEX/DOB: [REDACTED]

PT. HOME PHONE #: [REDACTED]

PT. TYPE: [REDACTED]

LOCATION: [REDACTED]

UNIT #: [REDACTED]

ORDERING PHYSICIAN: [REDACTED]

ACCOUNT #: [REDACTED]

ORDERING MD ADDRESS: [REDACTED]

ATTENDING PHYSICIAN: [REDACTED]

REFERRING PHYSICIAN: [REDACTED]

ORDERING MD PHONE: [REDACTED]

CONSULTING PHYSICIAN: [REDACTED]

Checkin-Exam Code Summary

Scans through the pelvis were obtained for localization of the pelvic fluid collection noted on the [REDACTED] CT pelvis exam.

The overlying skin was prepped and draped in a sterile fashion. A 19 gauge 15 cm length needle was inserted and advanced in an oblique fashion through the left buttock and directed medially into the 5 x 4 cm fluid collection to the left of the midline of the mid pelvis. Approximately 23 cc of clear yellow fluid was aspirated. Following removal of the 19 gauge needle, repeat scans through the pelvis were obtained and failed to demonstrate any evidence of post procedure hemorrhage. A small residual fluid collection is noted measuring approximately 1.6 cm x 0.7 cm indicating a marked decrease in the overall size of the fluid collection. The patient tolerated the procedure well. The patient was subsequently discharged from the Radiology Department following a short period of observation.

The fluid was sent for laboratory analysis.

IMPRESSION:

Technically successful pelvic fluid aspiration utilizing CT guidance and intravenous conscious sedation as described above.

Interpreted by: [REDACTED]

/Read By/ [REDACTED]

[REDACTED]

RADIOLOGY REPORT

[page 66 of 75]
DATE OF OPERATION:

+217

SURGEON:

ASSISTANTS:

PREOPERATIVE DIAGNOSIS:

ADHESIVE SMALL BOWEL OBSTRUCTION

POSTOPERATIVE DIAGNOSIS:

ADHESIVE SMALL BOWEL OBSTRUCTION

OPERATION:

EXPLORATORY LAPAROTOMY, LYSIS OF ADHESIONS
WITH REDUCTION OF SMALL BOWEL OBSTRUCTION,
RETROPERITONEAL BIOPSY TIMES TWO,
APPENDECTOMY

PREOP HISTORY:

The patient had undergone hysterectomy with bowel obstruction for apparently locally advanced cancer within the past year. She now presented with several days of progressive abdominal symptoms. CT scan was eventually obtained, consistent with high-grade partial small bowel obstruction. Discussion was held. She is prepared for the Operating Room.

PROCEDURE:

The old midline incision from just above the umbilicus to just above the symphysis pubis was utilized. There were multiple intra-abdominal adhesions. One of them created a tight band approximately at the level of the mid small bowel. There was very swollen and dilated bowel proximally and completely decompressed small bowel distally. The band was taken down along with the remainder of the adhesions so the small bowel could be run from the ligament of Treitz to the terminal ileum. There was no distinct peritoneal studding consistent with metastatic disease. There were no lesions palpable in the liver, although this was somewhat limited because of the high upper abdominal adhesions. Several of the thick adhesions were noted and one of these was sent as a biopsy. There was also a nodule deep in the pelvis on the anterior portion of the pouch of Douglas and this was excised as well and sent for pathology.

The appendix had been caught in the adhesions deep in the pelvis. It was felt as the patient never had appendicitis it would be difficult to diagnose. The mesentery was taken down by serial clamping, dividing and ligating the mesentery. The appendix was then divided at its junction with the cecum using the TA-30 stapler. There was good closure noted. The stump was inverted with a pursestring suture of silk.

CONTINUED

OPERATIVE REPORT

[page 67 of 75]
[REDACTED]

PAGE 2

PROCEDURE CONTINUED:

The abdomen was irrigated and aspirated, hemostasis assured. A JP drain was placed in the abdomen and eventually held in place with a stitch. The incision was closed with heavy Vicryl suture, the subcu irrigated, hemostasis assured and closed with staples.

[REDACTED]

JOB NO.: [REDACTED] [REDACTED] d [REDACTED] t. [REDACTED]

+217

+217

[REDACTED]

[REDACTED] [REDACTED] [REDACTED]

[REDACTED]

OPERATIVE REPORT

[page 68 of 75]
OPERATIVE REPORT

DATE OF SURGERY:

+0

PREOPERATIVE DIAGNOSIS:

Iron deficiency anemia to rule out colon cancer, pelvic mass.

POSTOPERATIVE DIAGNOSIS:

Mass lesion at the junctions of sigmoid and descending colon most consistent with primary carcinoma of the colon and a small benign polyp at the distal sigmoid colon, iron deficiency anemia.

OPERATIVE PROCEDURE:

Complete colonoscopy with biopsy and cautery.

ATTENDING PHYSICIAN:

SURGEON:

ANESTHESIA:

INDICATIONS FOR SURGERY:

A [REDACTED] was found to have pelvic mass on physical check-up like ovarian cancer at the same time was detected with iron deficiency anemia with hemoglobin of 8.7 and markedly low MCV of hypochromic microcytic anemia nature. She observed episodic small blood per rectum. She was advised to have colonoscopy three months ago but she was waiting for the right time. CAT scan showed segmental thickening of the sigmoid area.

OPERATIVE TECHNIQUE:

The patient was prepared with a Golytely without any problem.

Under local IV sedation, the colonoscope was inserted to the cecum without difficulty. The cecum, ileocecal valve, ascending colon, and transverse colon were normal. The ascending colon was normal. At the junction approximately of sigmoid colon and descending colon measured at 15 centimeters length during insertion of endoscope, there was a rigid annular solid ulcerated friable mass lesion approximately 5 centimeters long most consistent with primary colon cancer. Multiple biopsies were done. In the distal sigmoid colon at 20 centimeter level, there was a 6 millimeter sessile benign looking polyp, it was biopsied with cautery. The rectum and anal canal were normal. The patient tolerated the procedure well.

The patient will undergo surgical procedure today and she would have follow up evaluation around six to twelve months after the surgery of

PATIENT:

MR#

REFERRING PHYSICIAN:

OPERATIVE REPORT

COPY

Page 1 of 2

[page 69 of 75]
OPERATIVE REPORT

) the colon. She also should have CEA level checked. The findings were discussed with [REDACTED]

[REDACTED]
DD:

DT:

JOB#

CC:

PATIENT: [REDACTED]

MR# [REDACTED]

REFERRING PHYSICIAN: [REDACTED]

OPERATIVE REPORT

.D.

COPY

Page 2 of 2

[page 70 of 75]
DATE OF SURGERY: [REDACTED] +0

NOTE: This is a portion of this case of which there were several primaries.

PREOPERATIVE DIAGNOSIS: 1. Pelvic mass.
2. Colon carcinoma.

POSTOPERATIVE DIAGNOSIS: 1. Ovarian cancer stage III-C.
2. Colon cancer.

OPERATIVE PROCEDURE: Left ovarian cystectomy.

SURGEON: [REDACTED]

ASSISTANT: [REDACTED]

ESTIMATED BLOOD LOSS: 1000 cc.

IV FLUIDS: 7800 cc. crystalloid, 4 units packed red blood cells, and 1000 cc. Hcspan.

DRAINS: Foley to gravity and NG tube.

COMPLICATIONS:

INDICATIONS FOR SURGERY:

The patient is a [REDACTED] who reported a 4-month history of abdominal bloating and occasional rectal bleeding. A CT scan of the abdomen and pelvis performed on [REDACTED] revealed a septated 12 -19 centimeter pelvic mass and thickening of bowel wall. A colonoscopy performed on [REDACTED] revealed a mass in the colon near the splenic flexure.

+0

FINDINGS:

Under exploratory laparotomy, an approximately 12 centimeter left ovarian mass with both solid and cystic component, normal uterus, fallopian tubes, right ovary. An approximately 8 centimeter intraluminal mass was found within the lumen of the descending colon. Adherent to this mass was a loop of ileum. There was no evidence of tumor on the surface of the liver, spleen, or diaphragm. A few approximately 11.5 centimeter tumor nodules were found on the peritoneal surface on the left pelvis, and the several small implants were found within the omentum. One enlarged para-aortic lymph node was found.

PATIENT: [REDACTED]

MR# [REDACTED] REFERRING PHYSICIAN: [REDACTED]

OPERATIVE REPORT

[page 71 of 75]
PROCEDURE:

The patient was taken to the operating room where general anesthesia was found to be adequate. She was then examined under anesthesia with a large pelvic mass noted. She was then prepped and draped in the usual sterile fashion in the supine position. A vertical skin incision was made which extended around and above the umbilicus with the scalpel. This portion of the procedure was performed by Dr. [REDACTED]. After entry into the abdomen, prior to resection of the bowel, the large pelvic mass was excised by Dr. [REDACTED]. Two curved Heaney clamps were placed over the pedicle. Superior to these clamps, curved 8 clamps were placed and the tissue between transected with the Mayo scissors. Retraction of the mass during exploration of the abdominal cavity and during placement of the clamps, weakened section of the cyst wall and a small amount of the fluid contained within the ovarian mass was spilled on to the field, however, none of this material spilled into the abdominal cavity. The pedicles were then suture ligated with 0-Vicryl and the mass was sent for frozen section to pathology. Prior to excision of this mass, peritoneal fluid was aspirated and sent to cytology for evaluation. Good hemostasis was noted after suture ligation of the ovarian cyst pedicle. The remainder of the case, which includes large bowel resection, small bowel resection, total abdominal hysterectomy with bilateral salpingo-oophorectomy, omentectomy, bilateral pelvic and para-aortic lymph node dissections will be dictated separately by the primary surgeons Dr. [REDACTED]. This portion of the procedure only was performed by [REDACTED]. The patient was transferred in stable condition to the ICU.

+1

PATIENT: [REDACTED] REFERRING PHYSICIAN: [REDACTED] OPERATIVE REPORT
MR# [REDACTED]

[page 72 of 75]
OPERATIVE REPORT

DATE OF SURGERY: [REDACTED] +0

PREOPERATIVE DIAGNOSIS: Ovarian tumor, rule out ovarian carcinoma.

POSTOPERATIVE DIAGNOSIS: Ovarian carcinoma.

OPERATIVE PROCEDURE:

1. Staging laparotomy for ovarian carcinoma.
2. Total abdominal hysterectomy, right salpingo-oophorectomy.
3. Bilateral pelvic lymph node dissection.
4. Periaortic lymph node dissection.
5. Total omentectomy.

ATTENDING PHYSICIAN:

SURGEON:

ASSISTANT:

ANESTHESIA: General.

HISTORY:

This is a [REDACTED] with a history of pelvic and abdominal mass, whom I was consulted by Dr. [REDACTED] to evaluate the patient and recommend treatment. The patient's history and CAT scan were reviewed and she was examined. The CAT scan revealed a large solid and cystic pelvic tumor consistent with ovarian neoplasm. CAT scan also revealed a thickened rectosigmoid colon suspicious for tumor. Physical examination revealed a large pelvic and abdominal mass extending to the level of the umbilicus. There were no palpable peripheral lymph nodes. There is no nodularity. The abdomen was very obese, therefore I was not able to notice any abdominal ascites. Preoperative diagnosis was rule out ovarian carcinoma. Recommendation: The patient was advised to have exploratory laparotomy with resection of ovarian tumor, frozen section for further treatment would be advised. I did advise Dr. [REDACTED] that I would be stand-by until we had the pathologist's report and then intervene if needed.

INTRA-ABDOMINAL FINDINGS:

The patient was found to have a large left ovarian tumor, approximately 15 X 15 cm in diameter with necrosis and solid component. Frozen section was reviewed with the pathologist, which showed poorly differentiated adenocarcinoma consistent with ovarian

PATIENT: [REDACTED]
MR# [REDACTED] REFERRING PHYSICIAN: [REDACTED]

OPERATIVE REPORT

COPY

[page 73 of 75]
papillary carcinoma.

Exploration of the abdomen revealed palpable pelvic and low periaortic lymph nodes. The omentum was grossly negative. There were some adhesions between omentum and rectosigmoid colon at the site of colon lesion. The liver edges were smooth, gallbladder was negative. Kidneys and spleen with no gross abnormality. Upper abdomen did not reveal any gross lesion. The inferior surface of the right and left diaphragm were also negative for any metastasis. There were also some adhesions between a loop of small bowel to the rectosigmoid colon at the site of the colon carcinoma which was resected by Dr. [REDACTED]. He will be dictating that portion of the surgery.

PROCEDURE:

Under general anesthesia, in the supine position after prep and drape, pelvic examination was performed. The abdominal wall was opened by Dr. [REDACTED] and Dr. [REDACTED]. Ovarian tumor was identified, and then after removing the ovarian tumor, I did take the specimen down to pathology, frozen section was performed which was reviewed with the pathologist and confirmed adenocarcinoma of the ovary. After completion of colon resection and primary anastomosis, and also small bowel resection by Dr. [REDACTED] I was requested to scrub and perform the surgery as outlined above.

Exploration of the abdomen was completed as mentioned above. Then self retaining retractor was inserted, proper exposure was obtained. The bowel were packed out of the pelvic cavity. Then the pelvic organs were identified, uterus was grasped with two curved 8 clamps. Then, using two additional assistants, the pelvic organs were well exposed. The retroperitoneal space was well opened bilaterally from pelvic brim down to internal inguinal canal region. The anterior leaf of the broad ligament was excised and round ligaments were clamped, cut and sutured. Then the anterior leaf of the broad ligament was further excised and bladder flap was pushed and dissected off of anterior surface of the uterus and cervix. Then on the right side, retroperitoneal space was opened, ovarian vessels were identified at the pelvic brim and the ureter also was identified and ovarian vessels were doubly ligated with Ethibond #0 suture and transected. Then the retroperitoneal space was further developed. Paravesical and pararectal spaces were well developed and the ureter was followed all the way to the bladder and retracted laterally. The uterine vessels on the right side were identified at their origination from hypogastric vessels, they were separately ligated and transected with 2-0 Ethibond suture. At this time, uterosacral ligament on the right side was clamped, cut and sutured. Also on the left side, the uterine vessels were identified after exposing and dissecting the retroperitoneal space. They were clamped and ligated at their origination from hypogastric vessels. The uterosacral ligaments and cardinal ligaments were also clamped, cut and sutured. Then the

PATIENT: [REDACTED]

MR# [REDACTED]

REFERRING PHYSICIAN: [REDACTED]

OPERATIVE REPORT

COPY

[page 74 of 75]
rectum was further dissected off of the posterior surface of the cervix and vagina. Then the vaginal cuff was entered below the cervicovaginal junction, two Heaney clamps were applied on each corner, and specimen was resected and removed intact, uterus, cervix, right tube and ovary. The left tube and ovary were previously removed by Dr. [REDACTED]. Then the pelvic cavity was exposed and irrigated. Bleeders were all controlled. At this time, attention was made to pelvic nodes. As a part of surgical staging, bilateral pelvic lymph node dissection was performed from bifurcation of the aorta down to the internal inguinal canal region, common iliac, external iliac, internal iliac and obturator lymph nodes were all dissected, removed and sent to pathology for pathologic evaluation. Then attention was made to the periaortic region. There were a couple of palpable nodes at the bifurcation of the aorta, therefore the retroperitoneal space was opened, vena cava and aorta were identified and lymph node dissection was performed by removing fatty and lymphatic tissue over the aorta and vena cava and also between aorta and vena cava, these nodes were also sent to pathology. Then attention was made to the upper abdomen, as a part of the surgical staging and tumor debulking, total omentectomy was performed by removing omentum from transverse colon and greater curvature of the stomach. Bleeders were ligated with 2-0 Ethibond suture and total omentectomy was performed and sent to pathology. After omentectomy, exploration of the abdomen and pelvis were performed. Again, the small and large bowel were followed, there was no evidence of any gross residual disease. In the pelvic region, there was some nodularities in the pelvic cul-de-sac, mostly on the left side and posterior to the cervix, therefore a portion of the pelvic peritoneum together with tumor nodules which were ranging between 2 cm to several millimeters were all dissected and removed and sent to pathology together with uterine specimen. At this time, sponge count and instrument count were performed, they were all correct. Then the abdominal wall was closed with Ethibond #0 suture including fascia, rectus muscle and peritoneum together. The subcutaneous fat was approximated with 3-0 Vicryl suture and the skin was closed with surgical staples. The patient tolerated the procedure well. She was transferred to recovery in stable condition.

PATIENT: [REDACTED]
MR# [REDACTED] REFERRING PHYSICIAN: [REDACTED]

OPERATIVE REPORT

Page 3 of 4

COPY

[page 75 of 75]
OPERATIVE REPORT

DD: [REDACTED] DT: +4
JOB# [REDACTED]
CC: [REDACTED]

PATIENT: [REDACTED] [REDACTED]
MR# [REDACTED] REFERRING PHYSICIAN: [REDACTED] OPERATIVE REPORT

COPY

Page 4 of 4

Source: NCI Genomic Data Commons file efddc63a-0a3d-416c-b17f-aaea15a0da5d (ER0148 ER-AD7D Clinical Report_Redacted_Sanitized.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).